Somatic mutation profile of tumor specimen 8af80ae9-2088-4124-91fb-8d6c17 (aliquot 8af80ae9-2088-4124-91fb-8d6c17_D6_1) from CPTAC case 05CO044, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIB.
Specimen 8af80ae9-2088-4124-91fb-8d6c17: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76485cb5-ea16-4af1-8726-95e8e6c97dcc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen eb4fbb4e-3f5f-4f33-a7ac-be0306 (Blood Derived Normal), aliquot eb4fbb4e-3f5f-4f33-a7ac-be0306_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df7e5a86-c7b6-415c-98e6-525a04f2d44b

The open-access MAF lists 3,649 somatic variants for this specimen: 2,424 protein-altering or splice-affecting, 752 silent, 473 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,719, Silent 752, Frame Shift Del 424, Intron 270, Frame Shift Ins 91, Nonsense Mutation 82, 3'UTR 79, 5'UTR 43, Splice Site 42, RNA 41, Splice Region 32, In Frame Del 29.

Variants (750 of 3,649; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANTXR2 | c.314G>A p.G105D | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs137852902, CM033742; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASXL1 | c.1934del p.G645Vfs*58 | Frame Shift Del (DEL) | VAF 30/176 reads (17%) | hotspot (GDC flag); catalogued as rs750318549; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BCKDHB | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 134/601 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs776631396, CM034726, COSV57517736; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BMPR2 | c.2308del p.R770Gfs*2 | Frame Shift Del (DEL) | VAF 77/481 reads (16%) | catalogued as rs1085307380; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CFAP410 | c.331G>A p.V111M | Missense Mutation (SNP) | VAF 41/182 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs555164150, COSV57395660; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL6A1 | c.2122C>T p.Q708* | Nonsense Mutation (SNP) | VAF 62/262 reads (24%) | catalogued as rs1569519109; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DDX3X | c.871C>T p.R291* (on ENST00000399959; = p.R292* on NM_001356.5) | Nonsense Mutation (SNP) | VAF 28/126 reads (22%) | catalogued as rs1555953488, COSV67863341; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FGA | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 76/408 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909606, CM100506, CM930249, COSV57393361; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GALK1 | c.410del p.G137Vfs*27 | Frame Shift Del (DEL) | VAF 39/247 reads (16%) | catalogued as rs767329054, CD993840; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- HPS1 | c.972del p.M325Wfs*6 | Frame Shift Del (DEL) | VAF 37/176 reads (21%) | catalogued as rs281865082, CD982691; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- INA | c.562G>A p.G188R | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.061); catalogued as rs920363358, CM1512510; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KMT2A | c.2318del p.P773Rfs*8 | Frame Shift Del (DEL) | VAF 49/256 reads (19%) | catalogued as rs782297546; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MFRP | c.3del p.H2Tfs*100 (on ENST00000449574; = p.H384Tfs*94 on NM_031433.4) | Frame Shift Del (DEL) | VAF 70/313 reads (22%) | catalogued as rs587776595; ClinVar: pathogenic; called by mutect2, varscan2
- MSH6 | c.3261dup p.F1088Lfs*5 | Frame Shift Ins (INS) | VAF 46/258 reads (18%) | hotspot (GDC flag); catalogued as rs267608078; ClinVar: pathogenic; called by mutect2, varscan2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 38/184 reads (21%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- NEUROD1 | c.616dup p.H206Pfs*38 | Frame Shift Ins (INS) | VAF 52/269 reads (19%) | catalogued as rs387906384; ClinVar: pathogenic; called by mutect2, varscan2
- NOTCH3 | c.850G>A p.A284T | Missense Mutation (SNP) | VAF 107/389 reads (28%) | hotspot (GDC flag); SIFT tolerated (0.15); PolyPhen possibly damaging (0.692); catalogued as rs149307620; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 24/114 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- PIGO | c.2191del p.R731Vfs*17 | Frame Shift Del (DEL) | VAF 42/198 reads (21%) | catalogued as rs760848629; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PRX | c.1090C>T p.R364* | Nonsense Mutation (SNP) | VAF 77/335 reads (23%) | catalogued as rs144183238, CM116276; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- SCN2A | c.5644C>T p.R1882* | Nonsense Mutation (SNP) | VAF 134/598 reads (22%) | catalogued as rs796053166, CM162377, COSV99334228; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TGFB1 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 36/195 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs200482214, CM013795, COSV99700133; ClinVar: pathogenic; called by muse, mutect2, varscan2
- THRB | c.1351T>G p.F451V | Missense Mutation (SNP) | VAF 20/416 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1057519028, CM952174, BM1473709; ClinVar: likely pathogenic; called by muse, mutect2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 78/393 reads (20%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.267del p.S90Pfs*33 | Frame Shift Del (DEL) | VAF 43/199 reads (22%) | catalogued as rs587783062; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- WDR19 | c.641del p.L214* | Frame Shift Del (DEL) | VAF 28/133 reads (21%) | catalogued as rs587777348; ClinVar: pathogenic; called by mutect2, varscan2
- ABCA1 | c.1826C>T p.T609M | Missense Mutation (SNP) | VAF 61/316 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as rs755276277; called by muse, mutect2, varscan2
- ABCA2 | c.4685C>T p.T1562M (on ENST00000614293; = p.T1532M on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1319691871, COSV99686857; called by muse, mutect2, varscan2
- ABCA4 | c.4556C>T p.T1519M | Missense Mutation (SNP) | VAF 34/318 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs115859773, CM1213236; called by muse, mutect2
- ABCA6 | c.917del p.L306Yfs*7 | Frame Shift Del (DEL) | VAF 14/150 reads (9%) | catalogued as rs750282619, COSV52635694; called by mutect2, varscan2
- ABCA7 | c.1400G>A p.R467H | Missense Mutation (SNP) | VAF 47/193 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs764544689, COSV54032528; called by muse, mutect2, varscan2
- ABCA9 | c.750A>T p.Q250H | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV100382854; called by muse, mutect2, varscan2
- ABCB10 | c.961G>A p.V321M | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as rs780229410, COSV60621008; called by muse, mutect2, varscan2
- ABCG8 | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 126/488 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs758668360, COSV55393995; called by muse, mutect2, varscan2
- ABHD16A | c.1502G>A p.R501H | Missense Mutation (SNP) | VAF 49/283 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.215); catalogued as rs1271413764, COSV65451551; called by muse, mutect2, varscan2
- AC008397.2 | c.1353C>A p.Y451* | Nonsense Mutation (SNP) | VAF 22/86 reads (26%) | catalogued as rs752077587; called by muse, mutect2, varscan2
- AC068580.4 | c.228C>T p.D76= | Splice Region (SNP) | VAF 26/360 reads (7%) | catalogued as rs587780914; ClinVar: benign; called by muse, mutect2
- ACAD10 | c.305del p.L102Yfs*12 | Frame Shift Del (DEL) | VAF 12/72 reads (17%) | catalogued as rs1266702641; called by mutect2, pindel, varscan2
- ACLY | c.2362C>T p.R788W | Missense Mutation (SNP) | VAF 45/195 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.228); catalogued as rs782788159; called by muse, mutect2, varscan2
- ACSF2 | c.534dup p.K179Qfs*53 | Frame Shift Ins (INS) | VAF 29/169 reads (17%) | catalogued as rs1567855547; called by mutect2, pindel, varscan2
- ACTR5 | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 41/171 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as rs17853829, COSV99709862; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 66/132 reads (50%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ACVR2B | c.498del p.Y167Tfs*21 | Frame Shift Del (DEL) | VAF 44/252 reads (17%) | catalogued as rs1458653556; called by mutect2, pindel, varscan2
- ADAMTS10 | c.2293del p.Q765Sfs*7 | Frame Shift Del (DEL) | VAF 70/364 reads (19%) | catalogued as rs782743337; called by mutect2, pindel, varscan2
- ADAMTS18 | c.3153C>G p.N1051K | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.109); catalogued as rs769604667; called by muse, mutect2
- ADAT3 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs868340074; called by muse, mutect2, varscan2
- ADCY2 | c.2713G>A p.V905M | Missense Mutation (SNP) | VAF 38/180 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs368187458; called by muse, mutect2, varscan2
- ADCY5 | c.178del p.A60Rfs*2 | Frame Shift Del (DEL) | VAF 7/57 reads (12%) | catalogued as rs756172692; called by pindel, varscan2
- ADCY8 | c.1507G>A p.D503N | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.963); catalogued as rs1563724934, COSV53903301, COSV99651047; called by muse, mutect2, varscan2
- ADD2 | c.1970C>T p.T657M | Missense Mutation (SNP) | VAF 60/290 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.425); catalogued as rs371492015; called by muse, mutect2, varscan2
- ADGRF3 | c.1838A>G p.Q613R (on ENST00000311519 / NM_001145168.1; = p.Q414R on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/217 reads (21%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.588); catalogued as rs1210274987; called by muse, mutect2, varscan2
- ADGRF4 | c.1184C>T p.S395L | Missense Mutation (SNP) | VAF 64/295 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs775954938, COSV51950767; called by muse, mutect2, varscan2
- ADGRL3 | c.335G>A p.R112H (on ENST00000506720 / NM_001322402.2; = p.R44H on NM_015236.6) | Missense Mutation (SNP) | VAF 27/198 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1284975701, COSV72268248; called by muse, mutect2, varscan2
- ADRA1A | c.31A>G p.S11G | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1189407397; called by muse, mutect2, varscan2
- AFF2 | c.2552G>A p.G851D | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); catalogued as rs1047598664, COSV54007091; called by muse, mutect2
- AFG3L2 | c.945G>T p.E315D | Missense Mutation (SNP) | VAF 72/342 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs757352786; called by muse, mutect2, varscan2
- AGPS | c.1687del p.S563Lfs*5 | Frame Shift Del (DEL) | VAF 46/283 reads (16%) | catalogued as COSV51560747; called by mutect2, pindel, varscan2
- AHCTF1 | c.2519C>T p.S840F (on ENST00000366508; = p.S814F on NM_015446.5) | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs756809314, COSV100403755; called by mutect2, varscan2
- AHDC1 | c.4058C>T p.T1353M | Missense Mutation (SNP) | VAF 39/152 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757367512; called by muse, mutect2, varscan2
- AHNAK2 | c.12254C>T p.A4085V | Missense Mutation (SNP) | VAF 160/559 reads (29%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.963); catalogued as rs372676751; called by muse, mutect2, varscan2
- AICDA | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 50/267 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.082); catalogued as rs775620434, COSV57565073; called by muse, mutect2, varscan2
- AKAP6 | c.31del p.L11* | Frame Shift Del (DEL) | VAF 25/105 reads (24%) | catalogued as rs771895850; called by mutect2, pindel, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 25/110 reads (23%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- AKAP9 | c.116del p.K39Rfs*17 | Frame Shift Del (DEL) | VAF 45/180 reads (25%) | catalogued as COSV62339755; called by mutect2, varscan2
- ALCAM | c.662C>T p.S221L | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs746032698; called by muse, mutect2, varscan2
- ALG10B | c.886del p.S296Hfs*23 | Frame Shift Del (DEL) | VAF 64/388 reads (16%) | catalogued as rs1397842268; called by mutect2, varscan2
- ALG3 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 28/224 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747467847; called by muse, mutect2, varscan2
- ALMS1 | c.7019C>T p.T2340M | Missense Mutation (SNP) | VAF 84/347 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs577661314; called by muse, mutect2, varscan2
- ALOX5 | c.269C>T p.T90M | Missense Mutation (SNP) | VAF 74/314 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs551364951, COSV65551176; called by muse, mutect2, varscan2
- ALPK1 | c.2324G>A p.G775D | Missense Mutation (SNP) | VAF 37/257 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs182191501; called by muse, mutect2, varscan2
- AMBRA1 | c.1151G>A p.R384H (on ENST00000458649 / NM_001367468.1; = p.R294H on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.306); catalogued as rs958703115, COSV54054963; called by muse, mutect2, varscan2
- AMT | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 47/232 reads (20%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs150649086; called by muse, mutect2, varscan2
- AMZ1 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs771129948, COSV100406125; called by muse, mutect2, varscan2
- ANHX | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 78/345 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.268); catalogued as rs867269140; called by muse, mutect2, varscan2
- ANK3 | c.12420del p.K4140Nfs*15 (on ENST00000280772 / NM_001320874.2; = p.K661Nfs*15 on NM_001149.3) | Frame Shift Del (DEL) | VAF 22/119 reads (18%) | catalogued as rs1466658148; called by mutect2, pindel, varscan2
- ANKRD31 | c.1533del p.G512Vfs*20 | Frame Shift Del (DEL) | VAF 12/86 reads (14%) | catalogued as rs1279723268; called by mutect2, pindel, varscan2
- ANKRD34B | c.1289G>A p.R430Q | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.052); catalogued as rs577979631; called by muse, mutect2, varscan2
- ANKRD35 | c.1534del p.A512Lfs*46 | Frame Shift Del (DEL) | VAF 27/147 reads (18%) | catalogued as rs782150401; called by mutect2, pindel, varscan2
- ANO10 | c.974G>A p.C325Y | Missense Mutation (SNP) | VAF 42/233 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as COSV99428705; called by muse, mutect2, varscan2
- ANO9 | c.1490+1G>A p.X497_splice | Splice Site (SNP) | VAF 22/127 reads (17%) | catalogued as rs1263503204; called by muse, mutect2, varscan2
- ANOS1 | c.1531T>G p.S511A | Missense Mutation (SNP) | VAF 37/356 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV99391154; called by muse, mutect2, varscan2
- AOX1 | c.1298G>A p.R433Q | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs145889928; called by muse, mutect2, varscan2
- APBA1 | c.365A>G p.Y122C | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.533); catalogued as rs771450823, COSV55227839; called by muse, mutect2, varscan2
- APCDD1 | c.1049G>A p.G350D | Missense Mutation (SNP) | VAF 66/314 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758100126; called by muse, mutect2, varscan2
- APLNR | c.401C>A p.P134Q | Missense Mutation (SNP) | VAF 63/303 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.326); catalogued as COSV57242900; called by muse, mutect2, varscan2
- APLP2 | c.1603G>A p.V535M | Missense Mutation (SNP) | VAF 42/188 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs536665333, COSV53843723; called by muse, mutect2, varscan2
- APOE | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 67/280 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.036); catalogued as rs954186991; called by muse, mutect2, varscan2
- ARHGAP10 | c.1034G>A p.R345Q | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs759250334, COSV60601435; called by muse, mutect2, varscan2
- ARHGAP22 | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 10/173 reads (6%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs1258859082; called by muse, mutect2
- ARHGAP39 | c.1327G>A p.V443I | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV52773703; called by muse, mutect2
- ARHGEF40 | c.2209del p.A737Pfs*3 | Frame Shift Del (DEL) | VAF 20/83 reads (24%) | catalogued as rs749402223; called by mutect2, pindel, varscan2
- ARMC10 | c.557T>C p.V186A | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); catalogued as rs796193968; called by muse, mutect2, varscan2
- ARMCX2 | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 18/283 reads (6%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV100168208; called by muse, mutect2
- ART5 | c.257del p.P86Lfs*9 | Frame Shift Del (DEL) | VAF 39/231 reads (17%) | catalogued as COSV51707195; called by mutect2, pindel, varscan2
- ARX | c.851C>A p.T284K | Missense Mutation (SNP) | VAF 34/301 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs587783206; ClinVar: likely benign; called by muse, mutect2, varscan2
- ASAH2 | c.148del p.S50Qfs*40 | Frame Shift Del (DEL) | VAF 12/57 reads (21%) | catalogued as rs772181094; called by mutect2, varscan2
- ASB2 | c.338A>G p.Y113C | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.922); catalogued as COSV60114390; called by muse, mutect2
- ASCC3 | c.3434del p.K1145Sfs*7 | Frame Shift Del (DEL) | VAF 73/281 reads (26%) | catalogued as rs759097017; ClinVar: uncertain significance; called by mutect2, varscan2
- ASPM | c.5069A>T p.K1690M | Missense Mutation (SNP) | VAF 40/388 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV99660495; called by muse, varscan2
- ATAD1 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.741); catalogued as rs1302126882; called by muse, varscan2
- ATAD2 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54881389, COSV54888536; called by muse, mutect2, varscan2
- ATAD5 | c.688A>T p.K230* | Nonsense Mutation (SNP) | VAF 17/157 reads (11%) | catalogued as COSV58972719; called by muse, mutect2, varscan2
- ATAT1 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 58/202 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs1404181145; called by muse, mutect2, varscan2
- ATP10A | c.2414C>T p.A805V | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs201154784; called by muse, mutect2, varscan2
- ATP2B3 | c.1681G>C p.V561L | Missense Mutation (SNP) | VAF 29/263 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as COSV54858421; called by muse, mutect2, varscan2
- ATP2C1 | c.2387G>A p.R796H | Missense Mutation (SNP) | VAF 59/275 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.124); catalogued as rs1286861425, COSV60752585; called by muse, mutect2, varscan2
- ATXN7L2 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1223359486; called by muse, mutect2, varscan2
- AVPR1A | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 23/419 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.23); catalogued as COSV54547191; called by muse, mutect2
- B3GNT7 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs373797673; called by muse, mutect2, varscan2
- B3GNT9 | c.606del p.F202Lfs*3 | Frame Shift Del (DEL) | VAF 31/209 reads (15%) | catalogued as rs760854232; called by mutect2, pindel, varscan2
- B4GALT7 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.037); catalogued as COSV50352592; called by muse, mutect2
- BACE2 | c.259del p.D87Tfs*11 | Frame Shift Del (DEL) | VAF 3/21 reads (14%) | catalogued as COSV100160645; called by pindel, varscan2
- BAG6 | c.3200T>C p.I1067T (on ENST00000676571; = p.I1020T on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/276 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV99276473; called by muse, mutect2, varscan2
- BCLAF1 | c.892C>T p.R298* | Nonsense Mutation (SNP) | VAF 25/168 reads (15%) | catalogued as rs138333275, CM136163; called by muse, mutect2, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 37/180 reads (21%) | catalogued as rs768244116; called by mutect2, pindel, varscan2
- BCS1L | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 132/599 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs1354673459, COSV99829185; called by muse, mutect2, varscan2
- BICRA | c.4420C>T p.R1474W | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1215558782, COSV67604756; called by muse, mutect2, varscan2
- BMERB1 | c.538A>G p.S180G | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as rs578226555; called by muse, mutect2, varscan2
- BMP15 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 34/336 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs868942078, COSV53139709; called by muse, mutect2, varscan2
- BMP2 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 42/390 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.15); catalogued as rs1251797584, COSV66577768; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 77/202 reads (38%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BMX | c.33_35del p.L12del | In Frame Del (DEL) | VAF 13/136 reads (10%) | catalogued as rs773743068; called by pindel, varscan2
- BRD3 | c.71del p.P24Rfs*24 | Frame Shift Del (DEL) | VAF 19/82 reads (23%) | catalogued as rs763134487; called by mutect2, varscan2
- BRD8 | c.64C>T p.R22* | Nonsense Mutation (SNP) | VAF 17/118 reads (14%) | catalogued as rs757170202; called by muse, varscan2
- BRPF1 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 44/225 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs755029735, COSV57403970; called by muse, mutect2, varscan2
- BRPF3 | c.3557C>T p.A1186V | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1363623097, COSV100325570; called by muse, mutect2, varscan2
- BRWD1 | c.6926del p.L2309* | Frame Shift Del (DEL) | VAF 28/124 reads (23%) | catalogued as rs1455506786, COSV59000653; called by mutect2, varscan2
- BTBD9 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs749280771, COSV58426414; called by muse, mutect2, varscan2
- BTLA | c.424C>T p.R142* | Nonsense Mutation (SNP) | VAF 18/98 reads (18%) | catalogued as rs780433132, COSV57938030; called by muse, mutect2, varscan2
- C12orf4 | c.1256G>A p.R419Q | Missense Mutation (SNP) | VAF 29/245 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs559422887, COSV99712965; called by muse, mutect2, varscan2
- C14orf28 | c.74C>A p.P25H | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.533); catalogued as rs770707215; called by muse, mutect2, varscan2
- C16orf46 | c.116dup p.N39Kfs*11 | Frame Shift Ins (INS) | VAF 37/204 reads (18%) | catalogued as rs753533248; called by mutect2, varscan2
- C19orf81 | c.406C>T p.L136F | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1388427908; called by muse, mutect2, varscan2
- C2orf73 | c.309del p.F103Lfs*17 | Frame Shift Del (DEL) | VAF 29/98 reads (30%) | catalogued as rs747496393; called by mutect2, varscan2
- C4B | c.2509C>A p.L837I | Missense Mutation (SNP) | VAF 82/760 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV101426129; called by muse, mutect2, varscan2
- C4orf54 | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 40/263 reads (15%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs983110665; called by muse, mutect2, varscan2
- C5 | c.3711C>A p.S1237R | Missense Mutation (SNP) | VAF 52/291 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV56329282; called by muse, mutect2, varscan2
- C7orf57 | c.506del p.K169Sfs*2 | Frame Shift Del (DEL) | VAF 17/110 reads (15%) | catalogued as rs747591930; called by mutect2, varscan2
- C9orf78 | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV61029602; called by muse, mutect2, varscan2
- CACNA1D | c.1974del p.L659Sfs*44 (on ENST00000350061 / NM_001128840.3; = p.L679Sfs*44 on NM_000720.4) | Frame Shift Del (DEL) | VAF 122/580 reads (21%) | catalogued as COSV55463556; called by mutect2, pindel, varscan2
- CACNA1I | c.4819G>A p.A1607T | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs950143760; called by muse, mutect2, varscan2
- CACNA1S | c.4860del p.V1621Sfs*13 | Frame Shift Del (DEL) | VAF 105/306 reads (34%) | catalogued as rs761214441; called by mutect2, pindel, varscan2
- CALD1 | c.2225T>G p.V742G (on ENST00000361675 / NM_033138.4; = p.V487G on NM_004342.7) | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1193509877; called by muse, mutect2, varscan2
- CAPN9 | c.848T>C p.V283A | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs755650989; called by muse, mutect2, varscan2
- CARD10 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 60/248 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.137); catalogued as rs1467793360; called by muse, varscan2
- CARD11 | c.2377A>G p.M793V | Missense Mutation (SNP) | VAF 53/222 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs201921426; called by muse, mutect2, varscan2
- CARD8 | c.83T>C p.I28T | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as rs1200570928; called by muse, mutect2, varscan2
- CARD9 | c.1078-6C>T | Splice Region (SNP) | VAF 22/150 reads (15%) | catalogued as rs769142671; called by muse, varscan2
- CARMIL2 | c.2137A>G p.T713A | Missense Mutation (SNP) | VAF 38/183 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs756617665; called by muse, mutect2, varscan2
- CARMIL2 | c.3383G>A p.R1128Q | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs779712556, COSV54667201; called by muse, mutect2, varscan2
- CASQ1 | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 68/193 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.207); catalogued as COSV63624521; called by muse, mutect2, varscan2
- CBR3 | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 62/281 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as rs780228078; called by muse, varscan2
- CBX1 | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 32/168 reads (19%) | catalogued as COSV104387334; called by muse, mutect2, varscan2
- CCDC106 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1215761409; called by muse, mutect2, varscan2
- CCDC153 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs754420871; called by muse, mutect2, varscan2
- CCDC166 | c.1232G>A p.R411Q | Missense Mutation (SNP) | VAF 81/212 reads (38%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as rs1554616584; called by muse, mutect2, varscan2
- CCDC168 | c.5333C>T p.T1778M | Missense Mutation (SNP) | VAF 38/230 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs746463687; called by muse, mutect2, varscan2
- CCDC186 | c.1202C>G p.A401G | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as COSV100991136; called by muse, mutect2, varscan2
- CCDC50 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 65/293 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs776098971; called by muse, mutect2, varscan2
- CCDC73 | c.1341del p.E448Kfs*5 | Frame Shift Del (DEL) | VAF 30/133 reads (23%) | catalogued as rs747079826; called by mutect2, varscan2
- CCDC74A | c.776del p.P259Qfs*2 | Frame Shift Del (DEL) | VAF 18/105 reads (17%) | catalogued as rs772061983; called by mutect2, pindel, varscan2
- CCDC88B | c.3226C>T p.R1076W | Missense Mutation (SNP) | VAF 47/181 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs766659095; called by muse, mutect2, varscan2
- CCT8L2 | c.520C>A p.L174M | Missense Mutation (SNP) | VAF 56/260 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.374); catalogued as COSV100742994; called by muse, mutect2, varscan2
- CD247 | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 24/337 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as rs760895755, COSV62976678; called by muse, mutect2
- CD248 | c.707G>T p.S236I | Missense Mutation (SNP) | VAF 66/275 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.043); catalogued as rs763200019; called by muse, mutect2, varscan2
- CD72 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 36/187 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.054); catalogued as rs751000794, COSV52410977; called by muse, mutect2, varscan2
- CD8B | c.589C>T p.R197W | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.035); catalogued as rs751687141, COSV100514501; called by muse, mutect2, varscan2
- CDC14B | c.1172C>T p.S391F | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as rs1216335099; called by muse, mutect2, varscan2
- CDC16 | c.1606G>A p.A536T | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs965860341; called by muse, mutect2
- CDC42BPA | c.3941G>A p.C1314Y (on ENST00000334218 / NM_001366019.2; = p.C1301Y on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/252 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100505106; called by muse, mutect2
- CDCA7L | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 22/209 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs201734057, COSV62258479; called by muse, mutect2, varscan2
- CDH13 | c.304del p.H102Mfs*9 | Frame Shift Del (DEL) | VAF 30/141 reads (21%) | catalogued as COSV99231610; called by mutect2, pindel, varscan2
- CDH23 | c.2915C>T p.T972M | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.038); catalogued as rs762772276; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH24 | c.2135del p.P712Rfs*129 | Frame Shift Del (DEL) | VAF 12/53 reads (23%) | catalogued as rs752398646; called by mutect2, pindel, varscan2
- CDT1 | c.884G>A p.R295Q | Missense Mutation (SNP) | VAF 93/415 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs149521649; called by muse, mutect2, varscan2
- CELSR1 | c.5544dup p.T1849Dfs*23 | Frame Shift Ins (INS) | VAF 12/58 reads (21%) | catalogued as rs776824429; called by mutect2, varscan2
- CELSR2 | c.2035C>T p.R679W | Missense Mutation (SNP) | VAF 47/252 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1348122952, COSV99603807; called by muse, mutect2, varscan2
- CELSR3 | c.107del p.G36Afs*11 | Frame Shift Del (DEL) | VAF 15/65 reads (23%) | catalogued as COSV51078877; called by mutect2, pindel, varscan2
- CENPC | c.1723del p.T575Lfs*21 | Frame Shift Del (DEL) | VAF 62/383 reads (16%) | catalogued as rs1560431351; called by mutect2, pindel, varscan2
- CEP126 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 24/215 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142032267, COSV54826164; called by muse, mutect2
- CEP135 | c.1304G>A p.R435H | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs767691969; called by muse, mutect2, varscan2
- CEP350 | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 36/462 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs149644649; called by muse, mutect2
- CEP350 | c.5555G>A p.R1852H | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs761924454, COSV62598953, COSV62610047; called by muse, mutect2, varscan2
- CEP68 | c.1282G>T p.G428C | Missense Mutation (SNP) | VAF 37/184 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as COSV53125736; called by muse, mutect2, varscan2
- CERS3 | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs372884134; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 63/277 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as rs771639961; called by muse, mutect2, varscan2
- CFAP46 | c.2752G>A p.A918T | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.132); catalogued as rs936812377; called by muse, mutect2, varscan2
- CFC1 | c.241G>A p.G81R | Missense Mutation (SNP) | VAF 52/503 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs567136194, COSV52090420; called by muse, mutect2, varscan2
- CFHR5 | c.737C>T p.P246L | Missense Mutation (SNP) | VAF 39/350 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as rs1195424791, COSV56824194; called by muse, mutect2, varscan2
- CHADL | c.1883G>A p.S628N | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.331); catalogued as COSV99346397; called by muse, mutect2, varscan2
- CHAMP1 | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 54/281 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs1566791145; called by muse, mutect2, varscan2
- CHD8 | c.7181del p.K2394Rfs*36 (on ENST00000646647 / NM_001170629.2; = p.K2115Rfs*36 on NM_020920.4) | Frame Shift Del (DEL) | VAF 27/104 reads (26%) | catalogued as rs1306254828, COSV63036921; called by mutect2, pindel, varscan2
- CHRNA1 | c.1087G>A p.D363N (on ENST00000261007 / NM_001039523.3; = p.D338N on NM_000079.4) | Missense Mutation (SNP) | VAF 92/377 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as COSV53681480; called by muse, mutect2, varscan2
- CHRNA10 | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.019); catalogued as rs1385246856; called by muse, mutect2, varscan2
- CHRNA4 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.293); catalogued as rs1208475063; called by mutect2, varscan2
- CILP2 | c.2204G>A p.R735H | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52281610; called by muse, mutect2, varscan2
- CLASP1 | c.2054G>A p.R685Q | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as rs767923805, COSV55342733; called by muse, mutect2, varscan2
- CLDN23 | c.430G>A p.V144M | Missense Mutation (SNP) | VAF 36/216 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as rs755689685; called by muse, mutect2, varscan2
- CLIC6 | c.773A>G p.D258G | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs947429515; called by muse, mutect2, varscan2
- CLK3 | c.1882C>T p.R628W (on ENST00000395066 / NM_001130028.1; = p.R480W on NM_003992.4) | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.113); catalogued as rs920443187; called by muse, mutect2, varscan2
- CLSPN | c.2399del p.F800Sfs*37 | Frame Shift Del (DEL) | VAF 88/260 reads (34%) | catalogued as rs776068676; called by mutect2, pindel, varscan2
- CMTM5 | c.377del p.P126Rfs*55 | Frame Shift Del (DEL) | VAF 60/272 reads (22%) | catalogued as rs751921758; called by mutect2, varscan2
- CNGB3 | c.1807C>T p.R603C | Missense Mutation (SNP) | VAF 32/333 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1425590290; called by muse, mutect2
- CNNM1 | c.2521C>T p.P841S | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.029); catalogued as rs1288178322; called by muse, mutect2
- CNTN1 | c.1805-1G>A p.X602_splice | Splice Site (SNP) | VAF 36/206 reads (17%) | catalogued as COSV61642835; called by muse, mutect2, varscan2
- CNTN6 | c.1253del p.K418Sfs*63 | Frame Shift Del (DEL) | VAF 15/82 reads (18%) | catalogued as rs758676375; called by mutect2, varscan2
- CNTNAP2 | c.430G>A p.G144S | Missense Mutation (SNP) | VAF 66/314 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs534910637; called by muse, mutect2, varscan2
- CNTNAP2 | c.2650C>T p.R884W | Missense Mutation (SNP) | VAF 51/328 reads (16%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.964); catalogued as rs373383452; ClinVar: uncertain significance; called by muse, varscan2
- CNTNAP3 | c.3265G>A p.D1089N | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.566); catalogued as COSV99904126; called by muse, mutect2, varscan2
- COG7 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 38/204 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs766859040; called by muse, mutect2, varscan2
- COL10A1 | c.528G>T p.K176N | Missense Mutation (SNP) | VAF 112/454 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as rs377766909; called by muse, varscan2
- COL11A1 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 23/192 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.087); catalogued as rs1290800296; called by muse, mutect2, varscan2
- COL12A1 | c.5410C>T p.R1804W | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs201973949, COSV59391669, COSV59394570; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL1A1 | c.1478G>A p.R493H | Missense Mutation (SNP) | VAF 38/461 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs867732977; called by muse, mutect2
- COL5A2 | c.1549C>A p.P517T | Missense Mutation (SNP) | VAF 18/429 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.205); catalogued as rs1439154504, COSV66409286; called by muse, mutect2
- COL6A1 | c.2602G>A p.A868T | Missense Mutation (SNP) | VAF 58/312 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs574295337, COSV62613481; called by muse, mutect2, varscan2
- COL6A2 | c.1273C>T p.R425C | Missense Mutation (SNP) | VAF 33/201 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs761330909; called by muse, mutect2, varscan2
- COL6A3 | c.7255G>A p.G2419S | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0.148); catalogued as rs749446863, COSV55097823; called by muse, mutect2, varscan2
- COL6A3 | c.4720G>A p.G1574R | Missense Mutation (SNP) | VAF 107/356 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1340303980; called by muse, mutect2, varscan2
- COL6A3 | c.4270C>A p.R1424S | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV99798394; called by muse, mutect2, varscan2
- COL6A6 | c.210G>C p.Q70H | Missense Mutation (SNP) | VAF 64/251 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62032708; called by muse, mutect2, varscan2
- COL6A6 | c.2453G>A p.G818D | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs750212806; called by muse, mutect2, varscan2
- COL8A1 | c.767C>A p.P256H | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.954); catalogued as COSV53737257; called by muse, mutect2
- COL9A1 | c.848del p.P283Lfs*45 | Frame Shift Del (DEL) | VAF 30/162 reads (19%) | catalogued as rs941174282; called by mutect2, pindel, varscan2
- COPB2 | c.228G>T p.A76= | Splice Region (SNP) | VAF 22/99 reads (22%) | catalogued as COSV60813787; called by muse, mutect2, varscan2
- COPS6 | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 33/179 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57997896; called by muse, mutect2, varscan2
- COX16 | c.165del p.K55Nfs*2 | Frame Shift Del (DEL) | VAF 28/142 reads (20%) | catalogued as rs759241200; called by mutect2, varscan2
- COX7A1 | c.16-2A>G p.X6_splice | Splice Site (SNP) | VAF 22/94 reads (23%) | catalogued as rs1171614565; called by muse, mutect2, varscan2
- CPNE2 | c.1499G>A p.R500H | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs763115539; called by muse, mutect2, varscan2
- CRACDL | c.1131del p.A378Qfs*121 | Frame Shift Del (DEL) | VAF 21/113 reads (19%) | catalogued as rs767494728, COSV67408370; called by mutect2, pindel, varscan2
- CREB3L3 | c.103G>A p.G35S | Missense Mutation (SNP) | VAF 79/428 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.757); catalogued as rs201474344; called by muse, mutect2, varscan2
- CREBBP | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 45/214 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.162); catalogued as rs1285192047, COSV104387924; called by muse, mutect2, varscan2
- CROCC2 | c.2233C>T p.Q745* | Nonsense Mutation (SNP) | VAF 37/155 reads (24%) | catalogued as COSV70369412; called by muse, mutect2, varscan2
- CROCC2 | c.3436del p.D1146Tfs*13 | Frame Shift Del (DEL) | VAF 18/154 reads (12%) | catalogued as rs1255916134; called by mutect2, pindel, varscan2
- CROT | c.102del p.K34Nfs*6 | Frame Shift Del (DEL) | VAF 15/101 reads (15%) | catalogued as rs756999481; called by mutect2, pindel, varscan2
- CRYGA | c.476del p.G159Vfs*9 | Frame Shift Del (DEL) | VAF 29/100 reads (29%) | catalogued as rs762650691; called by mutect2, pindel, varscan2
- CS | c.173C>T p.T58M | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as rs754737940, COSV60832540; called by muse, mutect2, varscan2
- CSF1R | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 72/363 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs532877119, COSV53833750; called by muse, mutect2, varscan2
- CSMD2 | c.5347G>A p.A1783T | Missense Mutation (SNP) | VAF 48/398 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53911192; called by muse, varscan2
- CSMD3 | c.7793G>A p.R2598Q (on ENST00000297405 / NM_001363185.1; = p.R2494Q on NM_052900.3) | Missense Mutation (SNP) | VAF 94/276 reads (34%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.996); catalogued as rs139482857; called by muse, varscan2
- CSMD3 | c.2299G>A p.D767N (on ENST00000297405 / NM_001363185.1; = p.D663N on NM_052900.3) | Missense Mutation (SNP) | VAF 90/285 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52126201; called by muse, mutect2, varscan2
- CSPG4 | c.1361C>A p.P454H | Missense Mutation (SNP) | VAF 28/210 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57902700; called by muse, varscan2
- CSRNP3 | c.1439A>G p.Y480C | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1359208255; called by muse, mutect2
- CTAGE9 | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 69/438 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.038); catalogued as rs1183766103, COSV58418684; called by muse, mutect2, varscan2
- CTAGE9 | c.176del p.L59Cfs*27 | Frame Shift Del (DEL) | VAF 99/601 reads (16%) | catalogued as rs752217831; called by mutect2, pindel, varscan2
- CTNND2 | c.1009G>A p.V337M | Missense Mutation (SNP) | VAF 48/236 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.306); catalogued as rs368770402; called by muse, varscan2
- CTSA | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 72/368 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs778824488, COSV51941511; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTSW | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 53/231 reads (23%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.477); catalogued as rs147390159; called by muse, mutect2, varscan2
- CUL7 | c.3655C>T p.Q1219* | Nonsense Mutation (SNP) | VAF 73/367 reads (20%) | catalogued as rs760592812; called by muse, mutect2, varscan2
- CYFIP1 | c.2597G>A p.R866Q | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.754); catalogued as rs770398521; called by muse, mutect2, varscan2
- CYP1A2 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 60/289 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758124536, COSV59659850; called by muse, mutect2, varscan2
- CYP27C1 | c.868C>T p.R290W | Missense Mutation (SNP) | VAF 30/368 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs772606875; called by muse, mutect2
- CYRIA | c.208A>G p.N70D | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.102); catalogued as rs778888630; called by muse, mutect2, varscan2
- CYYR1 | c.286G>A p.V96M | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs139201954; called by mutect2, varscan2
- DAAM2 | c.3110A>G p.D1037G (on ENST00000274867 / NM_001201427.2; = p.D1036G on NM_015345.3) | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.05); catalogued as rs1240353306; called by muse, mutect2, varscan2
- DAPK1 | c.3493G>A p.A1165T | Missense Mutation (SNP) | VAF 73/378 reads (19%) | SIFT tolerated (0.96); PolyPhen benign (0.088); catalogued as rs765062357; called by muse, mutect2, varscan2
- DAZAP1 | c.770del p.P257Rfs*78 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | catalogued as COSV99245498; called by mutect2, varscan2
- DCAF12L2 | c.1192G>A p.A398T | Missense Mutation (SNP) | VAF 27/242 reads (11%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV63582809; called by muse, mutect2, varscan2
- DCAF4L2 | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 137/432 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as COSV60478406; called by muse, mutect2, varscan2
- DCAF8L1 | c.1345del p.R449Gfs*6 | Frame Shift Del (DEL) | VAF 69/479 reads (14%) | catalogued as COSV71595377; called by mutect2, pindel, varscan2
- DCLK1 | c.875G>A p.R292H | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.416); catalogued as rs56185003, COSV55171671, COSV55182610; called by muse, mutect2, varscan2
- DCST2 | c.763C>T p.P255S | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55053031; called by muse, mutect2, varscan2
- DDC | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 97/543 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs781573378, COSV63565129; called by muse, mutect2, varscan2
- DDX43 | c.1092del p.G365Vfs*2 | Frame Shift Del (DEL) | VAF 25/128 reads (20%) | catalogued as rs1424884917, COSV64836411; called by mutect2, pindel, varscan2
- DEFB136 | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.908); catalogued as rs755111812; called by muse, mutect2, varscan2
- DENND2C | c.708dup p.Y237Ifs*3 | Frame Shift Ins (INS) | VAF 18/176 reads (10%) | catalogued as rs771378748; called by mutect2, pindel
- DEPDC5 | c.532A>G p.S178G | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as rs758035240; called by muse, mutect2, varscan2
- DHRS3 | c.901C>T p.R301W | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs765027018, COSV66108832; called by muse, mutect2, varscan2
- DHRS9 | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 55/210 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.084); catalogued as COSV59140306; called by muse, mutect2, varscan2
- DHX34 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 66/331 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs553380305, COSV60898753; called by muse, mutect2, varscan2
- DHX37 | c.2504G>A p.R835Q | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as rs142687812; called by muse, mutect2, varscan2
- DHX57 | c.2195del p.L732Wfs*7 | Frame Shift Del (DEL) | VAF 14/86 reads (16%) | catalogued as rs749610132; called by mutect2, varscan2
- DIS3L2 | c.2170C>T p.R724* | Nonsense Mutation (SNP) | VAF 38/171 reads (22%) | catalogued as rs773260717; called by muse, mutect2
- DLGAP1 | c.2614G>T p.G872W | Missense Mutation (SNP) | VAF 49/164 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59807184; called by muse, mutect2, varscan2
- DLGAP2 | c.741G>T p.E247D | Missense Mutation (SNP) | VAF 51/392 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV70095102; called by muse, mutect2, varscan2
- DLGAP4 | c.2321C>T p.A774V (on ENST00000339266 / NM_001365621.1; = p.A771V on NM_014902.6) | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.094); catalogued as rs368916003; called by muse, mutect2, varscan2
- DMBX1 | c.740del p.G247Vfs*15 | Frame Shift Del (DEL) | VAF 20/156 reads (13%) | catalogued as COSV63601642, COSV63602450; called by mutect2, pindel, varscan2
- DNAH11 | c.9755del p.L3252Cfs*4 | Frame Shift Del (DEL) | VAF 31/117 reads (26%) | catalogued as rs1472494326; called by mutect2, pindel, varscan2
- DNAH12 | c.5197T>C p.Y1733H | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.03); catalogued as rs1278380147; called by muse, mutect2, varscan2
- DNAH12 | c.1847T>C p.I616T | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as rs1210961492; called by muse, mutect2, varscan2
- DNAH12 | c.503C>T p.S168L | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1006370903, COSV60855640, COSV60856070; called by muse, varscan2
- DNAH17 | c.8573T>C p.M2858T | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as rs759554203; called by muse, mutect2, varscan2
- DNAH17 | c.6919C>T p.R2307C | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs779251038, COSV67760113; called by muse, mutect2, varscan2
- DNAH17 | c.4325G>A p.S1442N | Missense Mutation (SNP) | VAF 45/238 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs781423546; called by muse, mutect2, varscan2
- DOCK3 | c.3766G>T p.E1256* | Nonsense Mutation (SNP) | VAF 7/72 reads (10%) | catalogued as COSV56537461; called by muse, mutect2
- DOK2 | c.1016del p.P339Lfs*69 | Frame Shift Del (DEL) | VAF 57/207 reads (28%) | catalogued as rs1192231037; called by mutect2, pindel, varscan2
- DPAGT1 | c.318C>A p.C106* | Nonsense Mutation (SNP) | VAF 36/418 reads (9%) | catalogued as COSV62615007; called by muse, mutect2
- DPP8 | c.134G>T p.R45L (on ENST00000341861 / NM_001320875.2; = p.R29L on NM_017743.6) | Missense Mutation (SNP) | VAF 45/204 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0.015); catalogued as COSV55683614; called by muse, mutect2, varscan2
- DPY19L1 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs762478422, COSV60581164; called by muse, mutect2, varscan2
- DUOX1 | c.3881G>A p.R1294Q | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs746050550, COSV58477409; called by muse, mutect2, varscan2
- DUOX2 | c.3191G>A p.G1064D | Missense Mutation (SNP) | VAF 87/388 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as rs1169445483; called by muse, mutect2, varscan2
- DVL2 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.194); catalogued as rs780268199, COSV50034912; called by muse, mutect2
- DYNC1H1 | c.9490C>T p.R3164* | Nonsense Mutation (SNP) | VAF 20/375 reads (5%) | catalogued as COSV100794846; called by muse, mutect2
- DYNC1H1 | c.12685-3del | Splice Region (DEL) | VAF 71/386 reads (18%) | catalogued as rs751203379; called by mutect2, pindel, varscan2
- DZIP1 | c.2418dup p.S807Ifs*14 (on ENST00000347108; = p.S788Ifs*14 on NM_014934.5) | Frame Shift Ins (INS) | VAF 26/162 reads (16%) | catalogued as rs765594416; called by mutect2, varscan2
- DZIP1L | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 42/208 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759170608, COSV100551594; called by muse, mutect2, varscan2
- EDA2R | c.140G>T p.R47L | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as rs763325503; called by muse, mutect2, varscan2
- EEF1A2 | c.1337G>C p.G446A | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV53207550; called by muse, mutect2, varscan2
- EFR3A | c.2245C>T p.R749C | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1473482447; called by muse, mutect2, varscan2
- EGLN3 | c.406G>A p.V136M | Missense Mutation (SNP) | VAF 57/191 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51655933; called by muse, mutect2, varscan2
- EGR3 | c.1121C>T p.A374V | Missense Mutation (SNP) | VAF 73/236 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as rs201598642; called by muse, mutect2, varscan2
- EHD2 | c.1192C>T p.R398W | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs1201923936; called by muse, mutect2, varscan2
- EHMT2 | c.2994+4C>T | Splice Region (SNP) | VAF 27/117 reads (23%) | catalogued as rs377255094; called by muse, mutect2, varscan2
- EIF2A | c.1688del p.N563Ifs*31 | Frame Shift Del (DEL) | VAF 30/106 reads (28%) | catalogued as COSV99855990; called by mutect2, pindel, varscan2
- EIF2B3 | c.450del p.A151Qfs*57 | Frame Shift Del (DEL) | VAF 16/88 reads (18%) | catalogued as rs748937918; called by mutect2, varscan2
- EIF5 | c.573_575del p.P192del | In Frame Del (DEL) | VAF 9/72 reads (13%) | catalogued as rs1271788271; called by pindel, varscan2
- EMILIN3 | c.1380dup p.W461Vfs*31 | Frame Shift Ins (INS) | VAF 16/100 reads (16%) | catalogued as rs759858342; called by mutect2, varscan2
- EML2 | c.82del p.A28Pfs*63 | Frame Shift Del (DEL) | VAF 13/62 reads (21%) | catalogued as rs997582141; called by mutect2, pindel, varscan2
- ENO4 | c.623del p.K208Rfs*32 (on ENST00000622726; = p.K207Rfs*32 on NM_001242699.2) | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | catalogued as rs761717176; called by mutect2, varscan2
- EPG5 | c.2595G>A p.W865* | Nonsense Mutation (SNP) | VAF 13/78 reads (17%) | catalogued as rs1160786631, COSV56346670; called by muse, mutect2, varscan2
- EPHA4 | c.1774G>T p.G592C | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56039571; called by muse, mutect2, varscan2
- EPHA5 | c.1249C>T p.R417W | Missense Mutation (SNP) | VAF 42/295 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs202046693, COSV56638771, COSV99899727; called by muse, mutect2, varscan2
- EPHB3 | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs1457050797; called by muse, mutect2, varscan2
- EPN1 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 44/203 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1268532752; called by muse, mutect2, varscan2
- EPPK1 | c.2497G>A p.A833T | Missense Mutation (SNP) | VAF 33/219 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.24); catalogued as rs782549936; called by muse, mutect2, varscan2
- EPX | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 42/195 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.129); catalogued as rs138562045; called by muse, mutect2, varscan2
- ERCC6L | c.3386_3388del p.E1129del | In Frame Del (DEL) | VAF 36/156 reads (23%) | catalogued as rs780485401; called by pindel, varscan2
- ESRRB | c.559C>T p.R187* | Nonsense Mutation (SNP) | VAF 33/341 reads (10%) | catalogued as rs1064442; called by muse, mutect2, varscan2
- EVI5L | c.1541G>A p.R514Q | Missense Mutation (SNP) | VAF 41/190 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1415437550; called by muse, mutect2, varscan2
- EXOC2 | c.1633G>A p.G545R | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as rs776276443; called by muse, mutect2, varscan2
- EXOC3L2 | c.1411C>A p.Q471K | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.155); catalogued as COSV52974317; called by muse, mutect2, varscan2
- EYA3 | c.844A>G p.M282V | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1458497523; called by muse, mutect2
- F8 | c.6284dup p.L2095Ffs*31 | Frame Shift Ins (INS) | VAF 60/267 reads (22%) | catalogued as CI096978; called by mutect2, pindel, varscan2
- FAM120A | c.2951G>A p.R984H | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.989); catalogued as rs368146089; called by muse, mutect2, varscan2
- FAM135B | c.1355G>A p.S452N | Missense Mutation (SNP) | VAF 52/220 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.023); catalogued as rs374136718; called by muse, varscan2
- FAM151A | c.351dup p.T118Hfs*5 | Frame Shift Ins (INS) | VAF 50/154 reads (32%) | catalogued as rs749953492; called by mutect2, varscan2
- FAM160B2 | c.1928A>G p.Y643C | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99249005; called by muse, mutect2, varscan2
- FAM166C | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 47/187 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs867201385, COSV61593820; called by muse, mutect2, varscan2
- FAM178B | c.619_621del p.E207del | In Frame Del (DEL) | VAF 18/98 reads (18%) | catalogued as rs1312726599; called by mutect2, pindel, varscan2
- FAM184A | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.003); catalogued as rs1228171582; called by muse, mutect2, varscan2
- FAM189B | c.1991G>A p.R664Q | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as rs766338074, COSV59170631; called by muse, mutect2
- FAM189B | c.503G>T p.G168V | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.037); catalogued as COSV56945363; called by muse, mutect2
- FAM47A | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 42/225 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0.211); catalogued as rs548369838, COSV60498816; called by muse, mutect2, varscan2
- FAM81A | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 48/252 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs1181338730, COSV55678546; called by muse, mutect2, varscan2
- FAM83C | c.977C>A p.P326H | Missense Mutation (SNP) | VAF 46/187 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV65584191; called by muse, mutect2, varscan2
- FAM83E | c.143C>T p.T48I | Missense Mutation (SNP) | VAF 38/253 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as rs1484181479; called by muse, mutect2, varscan2
- FAM98A | c.522del p.K174Nfs*2 | Frame Shift Del (DEL) | VAF 19/82 reads (23%) | catalogued as rs1237814873; called by mutect2, varscan2
- FANCF | c.80A>G p.D27G | Missense Mutation (SNP) | VAF 61/321 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.063); catalogued as COSV100541909; called by muse, mutect2, varscan2
- FANCG | c.1063C>A p.L355I | Missense Mutation (SNP) | VAF 66/310 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62719989; called by muse, mutect2, varscan2
- FASN | c.6512A>G p.N2171S | Missense Mutation (SNP) | VAF 74/364 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs777691032; called by muse, mutect2, varscan2
- FASTKD3 | c.343G>A p.V115M | Missense Mutation (SNP) | VAF 45/308 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs868466752; called by muse, mutect2, varscan2
- FAT1 | c.4628G>A p.R1543H | Missense Mutation (SNP) | VAF 58/301 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1050292453; called by muse, mutect2, varscan2
- FAT3 | c.6787G>A p.A2263T | Missense Mutation (SNP) | VAF 78/356 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.009); catalogued as rs777108809, COSV53071923; called by muse, mutect2, varscan2
- FAT4 | c.8447C>T p.A2816V | Missense Mutation (SNP) | VAF 50/210 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.046); catalogued as rs201838109; called by muse, mutect2, varscan2
- FBN3 | c.3047dup p.F1017Lfs*21 | Frame Shift Ins (INS) | VAF 13/83 reads (16%) | catalogued as rs762143704; called by mutect2, pindel, varscan2
- FBN3 | c.1803dup p.L602Afs*64 | Frame Shift Ins (INS) | VAF 22/116 reads (19%) | catalogued as rs772353703; called by mutect2, varscan2
- FBXL7 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 42/227 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV100309871; called by muse, mutect2, varscan2
- FBXO39 | c.341G>A p.G114D | Missense Mutation (SNP) | VAF 60/293 reads (20%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.998); catalogued as rs1030033745; called by muse, mutect2, varscan2
- FBXO42 | c.1453C>T p.R485* | Nonsense Mutation (SNP) | VAF 23/177 reads (13%) | catalogued as rs779190739, COSV65046236; called by muse, mutect2, varscan2
- FBXW11 | c.10G>T p.D4Y | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.62); catalogued as rs1243318371; called by muse, mutect2, varscan2
- FBXW5 | c.352-6G>A | Splice Region (SNP) | VAF 53/219 reads (24%) | catalogued as rs374535247; called by muse, mutect2, varscan2
- FCAMR | c.196dup p.R66Kfs*103 | Frame Shift Ins (INS) | VAF 19/88 reads (22%) | catalogued as rs750132652; called by mutect2, pindel, varscan2
- FCSK | c.2141G>A p.R714H | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs551672930, COSV55367385; called by muse, mutect2, varscan2
- FDX1 | c.272A>G p.D91G | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1325575395; called by muse, mutect2
- FDX1 | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs368983211, COSV52799844; called by muse, mutect2, varscan2
- FER1L5 | c.2819C>T p.A940V (on ENST00000623019; = p.A947V on NM_001293083.2) | Missense Mutation (SNP) | VAF 56/197 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1014851606; called by muse, mutect2, varscan2
- FER1L6 | c.3708del p.G1237Afs*10 | Frame Shift Del (DEL) | VAF 40/152 reads (26%) | catalogued as rs747094222, COSV67548414; called by mutect2, pindel, varscan2
- FES | c.1268C>T p.T423M | Missense Mutation (SNP) | VAF 25/206 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as rs1417576519; called by muse, mutect2, varscan2
- FGF9 | c.388C>A p.L130I | Missense Mutation (SNP) | VAF 15/261 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.886); catalogued as rs1379079857; called by muse, mutect2
- FGFR4 | c.2137C>T p.H713Y | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.492); catalogued as COSV52801039; called by muse, mutect2, varscan2
- FHDC1 | c.1315del p.T439Pfs*2 | Frame Shift Del (DEL) | VAF 20/97 reads (21%) | catalogued as rs1303890230; called by mutect2, pindel, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | catalogued as rs777980924; called by mutect2, pindel
- FKBP9 | c.991C>T p.R331* | Nonsense Mutation (SNP) | VAF 41/201 reads (20%) | catalogued as rs746683922; called by muse, mutect2, varscan2
- FLG | c.7250A>G p.Q2417R | Missense Mutation (SNP) | VAF 32/478 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.076); catalogued as COSV64237427; called by muse, mutect2
- FLG | c.1397G>T p.G466V | Missense Mutation (SNP) | VAF 163/466 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV64236425, COSV64244942; called by muse, mutect2, varscan2
- FLG | c.117G>T p.K39N | Missense Mutation (SNP) | VAF 16/316 reads (5%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.586); catalogued as COSV64241707, COSV64244634, COSV64245696; called by muse, mutect2
- FLNB | c.4051G>A p.V1351M | Missense Mutation (SNP) | VAF 48/219 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs1029522759, COSV55895749; called by muse, mutect2, varscan2
- FLRT2 | c.1003C>T p.R335W | Missense Mutation (SNP) | VAF 51/223 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs745818091, COSV58145614; called by muse, mutect2, varscan2
- FLYWCH1 | c.922G>A p.A308T (on ENST00000253928 / NM_001308068.2; = p.A307T on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/248 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.018); catalogued as rs746052226, COSV54143159, COSV54150213; called by muse, mutect2, varscan2
- FLYWCH1 | c.2089_2091del p.P697del (on ENST00000253928 / NM_001308068.2; = p.P696del on NM_020912.1 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 24/150 reads (16%) | catalogued as rs1185023173; called by mutect2, pindel, varscan2
- FOXD3 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs374048887; called by mutect2, varscan2
- FOXG1 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 40/268 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57394796; called by muse, mutect2, varscan2
- FOXK1 | c.896G>T p.S299I | Missense Mutation (SNP) | VAF 33/186 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs757808824; called by muse, mutect2, varscan2
- FOXL2 | c.576del p.K193Sfs*78 | Frame Shift Del (DEL) | VAF 6/58 reads (10%) | catalogued as CD025235; called by pindel, varscan2
- FRAS1 | c.3881A>G p.D1294G | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.276); catalogued as rs373207218; called by muse, mutect2, varscan2
- FREM1 | c.5177C>A p.P1726H | Missense Mutation (SNP) | VAF 18/189 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV66531331; called by muse, mutect2
- FRMPD4 | c.2689C>T p.R897W | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766899987, COSV66218280; called by muse, mutect2, varscan2
- FRYL | c.3707C>T p.P1236L | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.193); catalogued as rs1041770617, COSV51961041; called by muse, mutect2
- FXR2 | c.1981G>A p.A661T | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.012); catalogued as rs1400686935; called by muse, mutect2, varscan2
- FZD2 | c.907C>T p.R303C | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); catalogued as COSV59528505; called by muse, mutect2, varscan2
- FZD5 | c.480del p.R161Gfs*40 | Frame Shift Del (DEL) | VAF 21/126 reads (17%) | catalogued as rs1413162495; called by mutect2, pindel, varscan2
- GAB1 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs377700737; called by muse, mutect2, varscan2
- GABBR1 | c.2573G>A p.R858H | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs745435524, COSV63544249; called by muse, mutect2, varscan2
- GABRA1 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 41/249 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.036); catalogued as rs763403354, COSV50099444; called by muse, mutect2, varscan2
- GABRA5 | c.644T>C p.V215A | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.889); catalogued as rs772314090; called by muse, mutect2, varscan2
- GABRG1 | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.929); catalogued as rs769209641, COSV54955110; called by muse, mutect2, varscan2
- GADD45B | c.189G>C p.E63D | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs1478757278, COSV53126307; called by muse, mutect2, varscan2
- GAL3ST4 | c.869G>A p.G290D | Missense Mutation (SNP) | VAF 77/247 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.575); catalogued as rs901090009, COSV57585521; called by muse, mutect2, varscan2
- GALM | c.279G>T p.K93N | Missense Mutation (SNP) | VAF 12/191 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.036); catalogued as COSV55373564; called by muse, mutect2
- GALNT1 | c.940G>T p.D314Y | Missense Mutation (SNP) | VAF 37/167 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52452205; called by muse, mutect2, varscan2
- GALNT14 | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61105394; called by muse, mutect2, varscan2
- GANAB | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1255865163, COSV100647965, COSV60467543; called by muse, mutect2, varscan2
- GATA3 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 59/284 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV60519675; called by muse, mutect2, varscan2
- GATA3 | c.708del p.S237Afs*28 | Frame Shift Del (DEL) | VAF 28/148 reads (19%) | catalogued as rs771019738, COSV60522496; called by mutect2, pindel, varscan2
- GBA | c.914C>T p.P305L | Missense Mutation (SNP) | VAF 64/580 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as CD951718, CM950564, HM971737; called by muse, mutect2, varscan2
- GBX2 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 96/432 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100103545; called by muse, mutect2, varscan2
- GDAP1L1 | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1424565874, COSV61158982; called by muse, mutect2, varscan2
- GDF1 | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1219700063; called by muse, varscan2
- GDF10 | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 20/191 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as rs553093337; called by muse, mutect2, varscan2
- GDF7 | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as rs552371951; called by muse, varscan2
- GFI1B | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 47/206 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1016682120; called by muse, mutect2, varscan2
- GFRA1 | c.1300A>G p.K434E | Missense Mutation (SNP) | VAF 24/274 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0.01); catalogued as rs780155564; called by muse, mutect2
- GHDC | c.1498G>A p.A500T | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.448); catalogued as rs376472900; called by muse, mutect2, varscan2
- GIGYF1 | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.992); catalogued as rs150338156; called by muse, mutect2, varscan2
- GIMAP8 | c.452dup p.N151Kfs*12 | Frame Shift Ins (INS) | VAF 99/368 reads (27%) | catalogued as rs746795576; called by mutect2, varscan2
- GJA3 | c.259A>G p.T87A | Missense Mutation (SNP) | VAF 27/332 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs753107639; called by muse, mutect2
- GLB1L2 | c.586G>A p.V196M | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.904); catalogued as rs745922862, COSV100335031; called by muse, mutect2, varscan2
- GLI2 | c.1616G>A p.R539H (on ENST00000361492 / NM_001374353.1; = p.R556H on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/198 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58039598; called by muse, mutect2, varscan2
- GLI3 | c.2968C>T p.R990C | Missense Mutation (SNP) | VAF 59/225 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs978431561; called by muse, mutect2, varscan2
- GLUD1 | c.404A>G p.Y135C | Missense Mutation (SNP) | VAF 22/360 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as rs1034653371; called by muse, mutect2
- GLUD2 | c.172G>T p.A58S | Missense Mutation (SNP) | VAF 25/306 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV60152589; called by muse, mutect2
- GNA14 | c.187T>C p.Y63H | Missense Mutation (SNP) | VAF 42/192 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59020060; called by muse, mutect2, varscan2
- GNB2 | c.746C>T p.T249M | Missense Mutation (SNP) | VAF 74/418 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1193860550; called by muse, varscan2
- GNRH1 | c.272_274del p.K91del | In Frame Del (DEL) | VAF 33/188 reads (18%) | catalogued as rs762423253; called by pindel, varscan2
- GOLGA8Q | c.614A>G p.H205R | Missense Mutation (SNP) | VAF 32/440 reads (7%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1308844427; called by muse, mutect2
- GP5 | c.1151G>A p.R384H | Missense Mutation (SNP) | VAF 81/353 reads (23%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as rs781530104; called by muse, mutect2, varscan2
- GPAM | c.1676C>A p.P559H | Missense Mutation (SNP) | VAF 68/321 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100788182; called by muse, mutect2, varscan2
- GPAT2 | c.2222C>T p.A741V | Missense Mutation (SNP) | VAF 47/156 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs768902575, COSV64003511; called by muse, mutect2, varscan2
- GPD2 | c.275-1G>A p.X92_splice | Splice Site (SNP) | VAF 79/456 reads (17%) | catalogued as COSV60097503; called by muse, mutect2, varscan2
- GPR149 | c.1301A>T p.E434V | Missense Mutation (SNP) | VAF 64/202 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs1392365965; called by muse, mutect2, varscan2
- GPR18 | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 54/242 reads (22%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.95); catalogued as rs776777158; called by muse, mutect2, varscan2
- GPR61 | c.811del p.A271Pfs*42 | Frame Shift Del (DEL) | VAF 46/209 reads (22%) | catalogued as COSV63984107; called by mutect2, pindel, varscan2
- GPR61 | c.808G>A p.G270R | Missense Mutation (SNP) | VAF 50/210 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.132); catalogued as COSV63983768; called by mutect2, varscan2
- GPR68 | c.511G>A p.V171M | Missense Mutation (SNP) | VAF 30/275 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.975); catalogued as rs914155634, COSV53175437; called by muse, mutect2, varscan2
- GPR83 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 41/190 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); catalogued as rs764329324; called by muse, mutect2, varscan2
- GRAP2 | c.248G>T p.R83L | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV59996383, COSV59996418; called by muse, mutect2, varscan2
- GREB1 | c.4915C>T p.P1639S | Missense Mutation (SNP) | VAF 64/272 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.627); catalogued as COSV52188741; called by muse, mutect2, varscan2
- GRIA2 | c.2125G>A p.E709K | Missense Mutation (SNP) | VAF 30/210 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV52402787; called by muse, mutect2, varscan2
- GRIA4 | c.1277C>T p.P426L | Missense Mutation (SNP) | VAF 16/223 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as COSV56902408; called by muse, mutect2
- GRIK2 | c.2713G>T p.E905* | Nonsense Mutation (SNP) | VAF 12/179 reads (7%) | catalogued as rs1227281851, COSV59780376; called by muse, mutect2
- GRIK5 | c.1841C>T p.A614V | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs756032803, COSV53479514; called by muse, mutect2, varscan2
- GRIN2C | c.3487dup p.A1163Gfs*116 | Frame Shift Ins (INS) | VAF 41/198 reads (21%) | catalogued as rs1161699823; called by mutect2, pindel, varscan2
- GRM1 | c.3130G>A p.A1044T | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1347532771, COSV51111362; called by muse, mutect2, varscan2
- GRM8 | c.2158del p.H720Tfs*12 | Frame Shift Del (DEL) | VAF 17/115 reads (15%) | catalogued as COSV58842099; called by mutect2, pindel, varscan2
- GRTP1 | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369435574; called by muse, mutect2, varscan2
- GSTM3 | c.467del p.K156Sfs*30 | Frame Shift Del (DEL) | VAF 17/93 reads (18%) | catalogued as rs59389091; called by mutect2, pindel, varscan2
- GTF3C1 | c.1178T>C p.M393T | Missense Mutation (SNP) | VAF 36/175 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV62245542; called by muse, mutect2, varscan2
- GTF3C3 | c.1150G>A p.V384M | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); catalogued as rs200627790; called by muse, mutect2, varscan2
- GTPBP4 | c.1046A>C p.K349T | Missense Mutation (SNP) | VAF 43/216 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as rs1335953965; called by muse, mutect2, varscan2
- GUCY1A1 | c.2048del p.L683* | Frame Shift Del (DEL) | VAF 40/264 reads (15%) | catalogued as rs751481702, COSV56650103, COSV56656519; called by mutect2, pindel, varscan2
- GYG2 | c.340G>A p.G114R | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1201973951, COSV58550595; called by muse, mutect2, varscan2
- H6PD | c.652C>T p.R218* | Nonsense Mutation (SNP) | VAF 88/376 reads (23%) | catalogued as rs774520385, COSV66230390; called by muse, mutect2, varscan2
- HABP4 | c.1232C>T p.A411V | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766412891, COSV64515169; called by muse, mutect2, varscan2
- HARS2 | c.179del p.P60Qfs*14 | Frame Shift Del (DEL) | VAF 36/353 reads (10%) | catalogued as rs765457460; called by mutect2, pindel, varscan2
- HBQ1 | c.179G>A p.G60D | Missense Mutation (SNP) | VAF 53/311 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1293327401, COSV52265365; called by muse, mutect2, varscan2
- HCAR3 | c.974G>A p.R325H | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.38); catalogued as rs1359795011, COSV63672632; called by muse, mutect2, varscan2
- HCN4 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.013); catalogued as rs1567801801, COSV56083838; called by mutect2, varscan2
- HCRTR1 | c.835C>T p.R279W | Missense Mutation (SNP) | VAF 61/192 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs200965303; called by muse, mutect2, varscan2
- HDAC6 | c.1297C>T p.P433S | Missense Mutation (SNP) | VAF 20/229 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.135); catalogued as COSV100490829; called by muse, mutect2
- HEBP2 | c.593del p.N198Mfs*26 | Frame Shift Del (DEL) | VAF 56/240 reads (23%) | catalogued as rs769528102, COSV100874953; called by mutect2, varscan2
- HECW1 | c.1640C>T p.A547V | Missense Mutation (SNP) | VAF 47/233 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs777261023, COSV67826494; called by muse, mutect2, varscan2
- HELQ | c.196C>T p.L66F | Missense Mutation (SNP) | VAF 56/314 reads (18%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.013); catalogued as rs185984250; called by muse, mutect2, varscan2
- HELZ2 | c.3641G>A p.R1214H (on ENST00000467148 / NM_001037335.2; = p.R645H on NM_033405.3) | Missense Mutation (SNP) | VAF 22/265 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as rs769920759; called by muse, mutect2
- HFM1 | c.4200del p.F1400Lfs*25 | Frame Shift Del (DEL) | VAF 10/72 reads (14%) | catalogued as rs766204131; called by mutect2, pindel, varscan2
- HHIP | c.983G>A p.R328K | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.116); catalogued as COSV56845170; called by muse, mutect2, varscan2
- HHIPL1 | c.1315T>C p.W439R | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1306218991; called by mutect2, varscan2
- HJURP | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 64/251 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs185797643, COSV64978465; called by muse, mutect2, varscan2
- HLA-A | c.148G>T p.G50C | Missense Mutation (SNP) | VAF 124/561 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65141172; called by muse, mutect2, varscan2
- HLA-C | c.502C>T p.Q168* | Nonsense Mutation (SNP) | VAF 124/724 reads (17%) | catalogued as rs200392944; called by muse, mutect2, varscan2
- HS6ST3 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 40/197 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs1226165605, COSV100940109; called by muse, mutect2, varscan2
- HSPA5 | c.1595G>A p.R532H | Missense Mutation (SNP) | VAF 30/206 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as rs368840257; called by muse, mutect2, varscan2
- HTATSF1 | c.8G>A p.G3D | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.273); catalogued as COSV54478603; called by muse, mutect2, varscan2
- HYAL3 | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs142315421; called by muse, mutect2, varscan2
- HYAL4 | c.35G>A p.C12Y | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99772268; called by muse, mutect2, varscan2
- ICAM3 | c.1010T>C p.M337T | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1418742573; called by muse, mutect2, varscan2
- IDUA | c.1592G>A p.R531Q | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.24); catalogued as rs920228043, COSV56105224; called by muse, mutect2
- IFT122 | c.1837G>A p.V613M (on ENST00000348417 / NM_052989.3; = p.V554M on NM_018262.4) | Missense Mutation (SNP) | VAF 90/502 reads (18%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as rs745308803, COSV56205509; called by muse, mutect2, varscan2
- IGF2R | c.3949del p.D1317Tfs*27 | Frame Shift Del (DEL) | VAF 46/173 reads (27%) | catalogued as rs760021495; called by mutect2, varscan2
- IGHA2 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 131/448 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as rs113035575; called by muse, mutect2, varscan2
- IGHG3 | c.113C>T p.T38M | Missense Mutation (SNP) | VAF 117/444 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as rs1304569835; called by muse, mutect2, varscan2
- IGLV8-61 | c.197del p.P66Qfs*? | Frame Shift Del (DEL) | VAF 41/213 reads (19%) | catalogued as COSV66503192; called by mutect2, pindel, varscan2
- IKZF1 | c.56del p.P19Lfs*2 | Frame Shift Del (DEL) | VAF 25/88 reads (28%) | catalogued as COSV58783267; called by mutect2, pindel, varscan2
- IKZF1 | c.1452C>A p.H484Q | Missense Mutation (SNP) | VAF 37/249 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100498098; called by muse, mutect2, varscan2
- IL12B | c.925C>T p.R309W | Missense Mutation (SNP) | VAF 82/523 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as rs771683283, COSV51455193; called by muse, mutect2, varscan2
- IL16 | c.2102G>A p.R701Q | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as rs754491584; called by muse, mutect2, varscan2
- IL3RA | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.177); catalogued as rs1174496797; called by muse, mutect2, varscan2
- IMPDH1 | c.344C>T p.T115M (on ENST00000470772 / NM_001142573.2; = p.T201M on NM_000883.4) | Missense Mutation (SNP) | VAF 38/275 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.045); catalogued as rs530528335, CM060290, COSV58315908; called by muse, mutect2, varscan2
- INPP5A | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV100704510, COSV61246579; called by muse, mutect2, varscan2
- INTS6 | c.2036del p.G679Efs*32 | Frame Shift Del (DEL) | VAF 30/212 reads (14%) | catalogued as rs1566207698; called by mutect2, pindel, varscan2
- INTS6L | c.1705C>T p.R569* | Nonsense Mutation (SNP) | VAF 19/152 reads (13%) | catalogued as rs782713573; called by muse, mutect2, varscan2
- IRS2 | c.3857G>A p.R1286Q | Missense Mutation (SNP) | VAF 80/280 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.194); catalogued as rs778969682, COSV65479604, COSV65481002; called by muse, varscan2
- ISM1 | c.961A>G p.S321G | Missense Mutation (SNP) | VAF 37/239 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV52608107; called by muse, mutect2, varscan2
- ITGB5 | c.1213G>A p.V405I | Missense Mutation (SNP) | VAF 19/188 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV56149038, COSV56151028; called by muse, mutect2, varscan2
- ITGB6 | c.1190G>A p.G397D | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.447); catalogued as COSV51792390; called by muse, mutect2
- ITPR1 | c.2339C>A p.A780E (on ENST00000354582; = p.A765E on NM_002222.7) | Missense Mutation (SNP) | VAF 31/159 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as COSV56974314; called by muse, mutect2, varscan2
- ITPR2 | c.5513A>G p.D1838G | Missense Mutation (SNP) | VAF 41/172 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.193); catalogued as rs1436901924; called by muse, mutect2, varscan2
- JMJD6 | c.1156G>A p.G386R | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs762473661; called by mutect2, varscan2
- JMY | c.2699G>A p.R900H | Missense Mutation (SNP) | VAF 30/241 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs754451547, COSV104432697; called by muse, mutect2, varscan2
- JUND | c.252del p.D85Tfs*12 | Frame Shift Del (DEL) | VAF 18/65 reads (28%) | catalogued as rs1555702626, COSV53254483; called by mutect2, pindel, varscan2
- KCNB1 | c.856G>A p.V286M | Missense Mutation (SNP) | VAF 51/202 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as rs1194019938, COSV65566651; called by muse, mutect2, varscan2
- KCND1 | c.1368+7C>T | Splice Region (SNP) | VAF 11/136 reads (8%) | catalogued as rs782626555; called by muse, mutect2
- KCND1 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs181033799, COSV99501772; called by muse, mutect2, varscan2
- KCNIP2 | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.749); catalogued as rs775190231, COSV99493135; called by muse, mutect2, varscan2
- KCNK17 | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.125); catalogued as rs746646161, COSV100950155, COSV64685773; called by muse, mutect2, varscan2
- KCNMA1 | c.1297C>T p.R433W | Missense Mutation (SNP) | VAF 74/420 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1232485384, COSV54275172; called by muse, mutect2, varscan2
- KCNN4 | c.64_66del p.E22del | In Frame Del (DEL) | VAF 30/170 reads (18%) | catalogued as rs751361496; called by mutect2, pindel, varscan2
- KCTD20 | c.1210C>T p.R404W | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.965); catalogued as rs757829854; called by muse, mutect2, varscan2
- KCTD8 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 41/211 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs549391615, COSV63588118; called by muse, mutect2, varscan2
- KHSRP | c.1109C>T p.A370V | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV101231261; called by muse, mutect2, varscan2
- KIAA2012 | c.2536del p.T846Qfs*16 | Frame Shift Del (DEL) | VAF 12/56 reads (21%) | catalogued as rs753894409; called by mutect2, varscan2
- KIF14 | c.4349del p.N1450Mfs*7 | Frame Shift Del (DEL) | VAF 9/56 reads (16%) | catalogued as rs1471303941; called by mutect2, pindel, varscan2
- KIF1C | c.2168G>A p.R723H | Missense Mutation (SNP) | VAF 46/210 reads (22%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.284); catalogued as rs139701770; called by muse, mutect2, varscan2
- KIF26A | c.1855G>A p.G619S | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.879); catalogued as rs763185147; called by muse, varscan2
- KIF26A | c.3282del p.L1096Wfs*152 | Frame Shift Del (DEL) | VAF 28/170 reads (16%) | catalogued as rs745639630; called by mutect2, varscan2
- KIF26B | c.3199dup p.R1067Pfs*50 | Frame Shift Ins (INS) | VAF 30/207 reads (14%) | catalogued as rs1033206065; called by mutect2, pindel, varscan2
- KIRREL2 | c.1504C>G p.R502G | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.49); catalogued as rs201818071; called by muse, mutect2, varscan2
- KLF15 | c.254C>T p.T85M | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs769538730, COSV104407162; called by muse, mutect2, varscan2
- KLF4 | c.347C>A p.P116H | Missense Mutation (SNP) | VAF 48/286 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as rs866819239; called by muse, mutect2, varscan2
- KLHDC4 | c.1517G>T p.G506V | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.224); catalogued as COSV99566761; called by muse, mutect2, varscan2
- KLHDC8B | c.48del p.M17Cfs*59 | Frame Shift Del (DEL) | VAF 30/148 reads (20%) | catalogued as rs756907493; called by pindel, varscan2
- KLHL30 | c.1553C>T p.T518M | Missense Mutation (SNP) | VAF 70/278 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767478070; called by muse, mutect2, varscan2
- KLRF2 | c.169C>T p.H57Y | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs575845984, COSV73374419; called by muse, mutect2, varscan2
- KMT2A | c.2720C>T p.P907L | Missense Mutation (SNP) | VAF 47/230 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.045); catalogued as rs1555036710, COSV63283062, COSV63291151; called by muse, mutect2, varscan2
- KMT2C | c.8429A>G p.H2810R | Missense Mutation (SNP) | VAF 19/194 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as rs779206480; called by muse, mutect2
- KMT2D | c.12623del p.N4208Tfs*7 | Frame Shift Del (DEL) | VAF 15/107 reads (14%) | catalogued as rs146371387; called by mutect2, pindel, varscan2
- KMT2D | c.1873C>T p.R625C | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1434021544, COSV56493074; called by muse, varscan2
- KMT5C | c.1015C>G p.R339G | Missense Mutation (SNP) | VAF 49/166 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); catalogued as rs759558050; called by muse, mutect2, varscan2
- KRT2 | c.401G>A p.G134D | Missense Mutation (SNP) | VAF 40/260 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.973); catalogued as rs1565640773; called by muse, varscan2
- KRT40 | c.1142G>A p.R381Q | Missense Mutation (SNP) | VAF 40/217 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.382); catalogued as rs541006199; called by muse, mutect2, varscan2
- KRT84 | c.1492C>T p.P498S | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.942); catalogued as rs1228575602; called by muse, mutect2, varscan2
- KRT86 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 28/552 reads (5%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1169609517, COSV53292210, COSV53292833; called by muse, mutect2
- KRTAP2-3 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1419450569; called by muse, mutect2, varscan2
- LARGE1 | c.1663A>G p.S555G | Missense Mutation (SNP) | VAF 58/287 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs760507626; called by muse, mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 21/112 reads (19%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LGI3 | c.114del p.C39Afs*31 | Frame Shift Del (DEL) | VAF 6/61 reads (10%) | catalogued as rs1232711946; called by pindel, varscan2
- LIG3 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.293); catalogued as rs202243099, COSV99253120; called by muse, mutect2, varscan2
- LINGO3 | c.1489G>A p.V497M | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1269982078, COSV68261345; called by muse, mutect2, varscan2
- LIPE | c.1886G>A p.R629Q | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.652); catalogued as rs760194099, COSV99734343; called by muse, mutect2, varscan2
- LLGL1 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs755966163; called by muse, mutect2, varscan2
- LMOD3 | c.444A>T p.E148D | Missense Mutation (SNP) | VAF 39/176 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs185938792, COSV70455916; called by muse, mutect2, varscan2
- LONRF3 | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.012); catalogued as rs1394889454; called by muse, mutect2, varscan2
- LOXL4 | c.1264C>T p.R422C | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750542694, COSV53254839; called by muse, mutect2, varscan2
- LPIN3 | c.1714G>A p.V572M | Missense Mutation (SNP) | VAF 43/177 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.621); catalogued as rs751703541; called by muse, mutect2, varscan2
- LRATD1 | c.616_618del p.E206del | In Frame Del (DEL) | VAF 22/122 reads (18%) | catalogued as rs749747903; called by pindel, varscan2
- LRBA | c.7013G>A p.R2338Q | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs962171895, COSV63952667; called by muse, mutect2
- LRFN2 | c.1777G>A p.G593R | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.67); catalogued as rs751087735, COSV57827011, COSV57828227; called by muse, mutect2, varscan2
- LRP2 | c.9031A>G p.R3011G | Missense Mutation (SNP) | VAF 72/264 reads (27%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.999); catalogued as rs1387989268; called by muse, mutect2, varscan2
- LRP3 | c.1466G>T p.C489F | Missense Mutation (SNP) | VAF 44/225 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs1385429809; called by muse, mutect2, varscan2
- LRP4 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 94/395 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as rs770467186; called by muse, mutect2, varscan2
- LRP5 | c.4078G>A p.D1360N | Missense Mutation (SNP) | VAF 60/228 reads (26%) | SIFT tolerated (0.26); PolyPhen probably damaging (1); catalogued as rs751601938, COSV53717418; called by muse, mutect2, varscan2
- LRRC7 | c.556G>A p.A186T (on ENST00000651989 / NM_001370785.2; = p.A153T on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 67/160 reads (42%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs766366739, COSV99226080; called by muse, mutect2, varscan2
- LRRC71 | c.991C>T p.R331* | Nonsense Mutation (SNP) | VAF 14/246 reads (6%) | catalogued as rs985264311; called by muse, mutect2
- LRRC8C | c.2237C>T p.P746L | Missense Mutation (SNP) | VAF 24/217 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as rs749404793, COSV64999276, COSV65000461; called by muse, mutect2, varscan2
- LRRFIP1 | c.1267G>A p.V423M (on ENST00000392000 / NM_001137552.2; = p.V399M on NM_004735.4) | Missense Mutation (SNP) | VAF 40/248 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as rs751075548; called by muse, mutect2, varscan2
- LRRK1 | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 17/177 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.307); catalogued as rs554667646, COSV52609368; called by muse, mutect2, varscan2
- LRRK1 | c.3997G>A p.A1333T | Missense Mutation (SNP) | VAF 59/252 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1029846060; called by muse, mutect2, varscan2
- LRRTM4 | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 22/348 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV69139030, COSV69142914; called by muse, mutect2
- MAEA | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 52/258 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs776869127, COSV53264821; called by muse, varscan2
- MAG | c.361C>A p.L121M | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV62698971; called by muse, mutect2, varscan2
- MAGEC1 | c.2197G>A p.G733R | Missense Mutation (SNP) | VAF 73/283 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1472714637, COSV53578402, COSV53579831; called by muse, mutect2, varscan2
- MALRD1 | c.4810G>A p.A1604T | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as rs769269357; called by muse, mutect2
- MAMDC4 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 47/198 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs769996411, CM142478; called by muse, mutect2, varscan2
- MAP9 | c.1700del p.K567Rfs*13 | Frame Shift Del (DEL) | VAF 30/145 reads (21%) | catalogued as rs1215313075; called by mutect2, varscan2
- MAPK15 | c.1532del p.Q511Rfs*? | Frame Shift Del (DEL) | VAF 46/158 reads (29%) | catalogued as rs1314162119; called by mutect2, pindel, varscan2
- MAPK8IP2 | c.1651G>A p.A551T | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.041); catalogued as rs771313856; called by muse, mutect2, varscan2
- MAS1L | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as rs183530034, COSV65809775; called by muse, mutect2, varscan2
- MAU2 | c.1114dup p.R372Pfs*61 | Frame Shift Ins (INS) | VAF 29/153 reads (19%) | catalogued as rs1226778907; called by mutect2, pindel, varscan2
- MB21D2 | c.1222G>A p.A408T | Missense Mutation (SNP) | VAF 36/230 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.132); catalogued as COSV99061949; called by muse, mutect2, varscan2
- MCM3AP | c.3808G>A p.V1270M | Missense Mutation (SNP) | VAF 49/279 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.14); catalogued as rs777057473; called by muse, mutect2, varscan2
- MCOLN1 | c.1414G>A p.D472N | Missense Mutation (SNP) | VAF 49/294 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs760411989, COSV51175191; called by muse, mutect2, varscan2
- MED1 | c.437del p.N146Ifs*24 | Frame Shift Del (DEL) | VAF 12/72 reads (17%) | catalogued as COSV56125174; called by mutect2, pindel, varscan2
- MED10 | c.323T>C p.L108P | Missense Mutation (SNP) | VAF 31/218 reads (14%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.995); catalogued as COSV55385698; called by muse, mutect2, varscan2
- MED25 | c.189del p.T64Pfs*150 | Frame Shift Del (DEL) | VAF 61/299 reads (20%) | catalogued as COSV57208404; called by mutect2, pindel, varscan2
- METAP1 | c.1135C>T p.R379W | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.466); catalogued as rs998073773, COSV56445818; called by muse, mutect2, varscan2
- MGA | c.3744del p.E1249Rfs*42 | Frame Shift Del (DEL) | VAF 20/157 reads (13%) | catalogued as rs1193719928; called by mutect2, pindel, varscan2
- MGAT3 | c.1367G>A p.R456H | Missense Mutation (SNP) | VAF 60/276 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV57869217; called by muse, mutect2, varscan2
- MGAT4D | c.1078A>G p.I360V | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.201); catalogued as rs1033291863; called by muse, mutect2, varscan2
- MGAT4D | c.176del p.N59Ifs*5 | Frame Shift Del (DEL) | VAF 19/89 reads (21%) | catalogued as rs1373232850; called by mutect2, pindel, varscan2
- MIB2 | c.2680G>A p.E894K | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV61543588; called by muse, mutect2, varscan2
- MICAL3 | c.4495del p.R1499Gfs*106 | Frame Shift Del (DEL) | VAF 20/119 reads (17%) | catalogued as rs765803753; called by mutect2, pindel, varscan2
- MIDN | c.835del p.V279Sfs*32 | Frame Shift Del (DEL) | VAF 32/156 reads (21%) | catalogued as COSV56294522; called by mutect2, pindel, varscan2
- MIS18BP1 | c.2278A>G p.M760V | Missense Mutation (SNP) | VAF 90/282 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100172719; called by muse, mutect2, varscan2
- MLLT6 | c.1162C>T p.P388S | Missense Mutation (SNP) | VAF 39/172 reads (23%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.796); catalogued as rs767245517; called by muse, mutect2, varscan2
- MMP19 | c.905G>T p.G302V | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.254); catalogued as COSV104400570; called by muse, mutect2, varscan2
- MMP24 | c.1714_1716del p.K572del | In Frame Del (DEL) | VAF 30/163 reads (18%) | catalogued as rs757961147; called by mutect2, pindel, varscan2
- MNDA | c.718G>A p.V240M | Missense Mutation (SNP) | VAF 61/174 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs996771509; called by muse, mutect2, varscan2
- MOB3B | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.063); catalogued as rs756949269; called by muse, varscan2
- MORC2 | c.485T>C p.V162A (on ENST00000397641 / NM_001303256.3; = p.V100A on NM_014941.3) | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.038); catalogued as COSV99309878; called by muse, mutect2, varscan2
- MPDZ | c.608A>G p.Q203R | Missense Mutation (SNP) | VAF 29/181 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs767504930; called by muse, mutect2, varscan2
- MRC2 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 16/155 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.38); catalogued as rs370889422, COSV57643896; called by mutect2, varscan2
- MROH2B | c.4088G>A p.C1363Y | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.939); catalogued as rs1363726686; called by muse, mutect2
- MRPS30 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as rs534375825, COSV50181666; called by muse, varscan2
- MSANTD3-TMEFF1 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs776217356, COSV58494679; called by muse, mutect2, varscan2
- MST1R | c.3742C>T p.R1248C | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.213); catalogued as rs372063160, COSV99617987; called by muse, mutect2, varscan2
- MTCL1 | c.3473G>A p.R1158H (on ENST00000306329 / NM_001378206.1; = p.R839H on NM_015210.4) | Missense Mutation (SNP) | VAF 66/232 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as rs777907534; called by muse, varscan2
- MTHFD2L | c.800C>T p.A267V (on ENST00000395759 / NM_001144978.2; = p.A209V on NM_001004346.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1256233569; called by muse, mutect2, varscan2
- MTMR1 | c.1056G>T p.K352N | Missense Mutation (SNP) | VAF 8/127 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV64892941; called by muse, mutect2
- MTMR3 | c.588A>G p.I196M | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as rs767507024; called by muse, mutect2, varscan2
- MTMR9 | c.584del p.N195Mfs*4 | Frame Shift Del (DEL) | VAF 18/70 reads (26%) | catalogued as rs767880823; called by mutect2, varscan2
- MTR | c.3452C>T p.A1151V | Missense Mutation (SNP) | VAF 51/252 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV63966107; called by muse, mutect2, varscan2
- MUC16 | c.35359C>A p.P11787T | Missense Mutation (SNP) | VAF 15/184 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV67446836, COSV67493766; called by muse, mutect2
- MUC19 | c.424del p.Y142Mfs*99 | Frame Shift Del (DEL) | VAF 20/87 reads (23%) | catalogued as rs776041179; called by pindel, varscan2
- MXI1 | c.662G>A p.S221N | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); catalogued as rs369868784, COSV53292633; called by muse, varscan2
- MXRA8 | c.901del p.R301Gfs*107 | Frame Shift Del (DEL) | VAF 17/114 reads (15%) | catalogued as rs764857791; called by mutect2, pindel, varscan2
- MYADM | c.388C>A p.H130N | Missense Mutation (SNP) | VAF 61/330 reads (18%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.629); catalogued as COSV100425191; called by muse, varscan2
- MYBPC1 | c.1229C>T p.A410V (on ENST00000550270 / NM_206820.2; = p.A435V on NM_002465.4) | Missense Mutation (SNP) | VAF 65/295 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as rs770140839, COSV100637730; called by muse, mutect2, varscan2
- MYBPHL | c.337C>T p.R113* | Nonsense Mutation (SNP) | VAF 30/129 reads (23%) | catalogued as rs191294010; called by muse, mutect2, varscan2
- MYH11 | c.4623G>A p.M1541I | Missense Mutation (SNP) | VAF 81/336 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs1358300741, COSV55565736; called by muse, mutect2, varscan2
- MYH13 | c.3149C>T p.A1050V | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs1478875991; called by muse, mutect2, varscan2
- MYH2 | c.533+1G>A p.X178_splice | Splice Site (SNP) | VAF 61/341 reads (18%) | catalogued as rs754104695, COSV55431803; called by muse, mutect2, varscan2
- MYH6 | c.5513C>T p.S1838L | Missense Mutation (SNP) | VAF 91/403 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as rs747673552; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH7 | c.2359C>T p.R787C | Missense Mutation (SNP) | VAF 115/448 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.485); catalogued as rs145677314, CM081705; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- MYO1F | c.3157G>A p.V1053M | Missense Mutation (SNP) | VAF 47/263 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.276); catalogued as rs765836759; called by muse, mutect2, varscan2
- MYO1G | c.2050G>A p.V684M | Missense Mutation (SNP) | VAF 22/334 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs867414113; called by muse, mutect2
- MYO5A | c.1714G>A p.V572I | Missense Mutation (SNP) | VAF 51/207 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); catalogued as rs757786338; called by muse, mutect2, varscan2
- MYOD1 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51453801; called by muse, mutect2, varscan2
- MYOM1 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.791); catalogued as COSV55301270; called by muse, mutect2, varscan2
- NAALADL2 | c.2120T>C p.M707T | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV101495204; called by muse, mutect2
- NALCN | c.4819C>T p.R1607W | Missense Mutation (SNP) | VAF 44/183 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs866709006, COSV51915914; called by muse, mutect2, varscan2
- NANS | c.211T>C p.Y71H | Missense Mutation (SNP) | VAF 55/236 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as rs770845183; called by muse, mutect2, varscan2
- NAT8L | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as rs778094880; called by muse, mutect2, varscan2
- NCAPD3 | c.3520A>G p.M1174V | Missense Mutation (SNP) | VAF 65/311 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs779306612; called by muse, mutect2, varscan2
- NCAPH2 | c.1792G>A p.A598T | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.84); PolyPhen benign (0.012); catalogued as rs1345914668; called by muse, mutect2
- NCK2 | c.729G>T p.Q243H | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.586); catalogued as rs1440465020; called by muse, mutect2, varscan2
- NCMAP | c.25del p.D9Ifs*7 | Frame Shift Del (DEL) | VAF 11/117 reads (9%) | catalogued as rs1557601718; called by mutect2, pindel, varscan2
- NCOA5 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764153135, COSV51648018; called by muse, mutect2, varscan2
- NDNF | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as rs202087102, COSV65632597; called by muse, mutect2, varscan2
- NEB | c.19220G>A p.R6407Q | Missense Mutation (SNP) | VAF 43/156 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.703); catalogued as rs745615279, COSV51441238, COSV51460697; called by muse, mutect2, varscan2
- NEDD9 | c.2038G>A p.V680M | Missense Mutation (SNP) | VAF 32/182 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758259305; called by muse, mutect2, varscan2
- NES | c.1176del p.T393Hfs*9 | Frame Shift Del (DEL) | VAF 42/133 reads (32%) | catalogued as rs759081520; called by mutect2, varscan2
- NES | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768415353; called by muse, mutect2
- NETO1 | c.1301G>A p.G434E | Missense Mutation (SNP) | VAF 19/372 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55005905; called by muse, mutect2
- NFKB2 | c.2447G>A p.S816N | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.702); catalogued as rs775029821; called by muse, mutect2, varscan2
- NHLH2 | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 20/229 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1451716726, COSV57202528; called by muse, mutect2
- NKX1-1 | c.529G>A p.G177S | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated, low confidence (0.05); catalogued as rs1178066868; called by muse, varscan2
- NKX2-1 | c.23C>T p.T8M | Missense Mutation (SNP) | VAF 50/250 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV61388770, COSV61390604; called by muse, mutect2, varscan2
- NLGN2 | c.1891C>T p.P631S | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as rs772692815; called by mutect2, varscan2
- NLRP2 | c.3113del p.N1038Tfs*4 | Frame Shift Del (DEL) | VAF 41/263 reads (16%) | catalogued as rs745782532; called by mutect2, pindel, varscan2
- NMUR2 | c.616G>A p.V206I | Missense Mutation (SNP) | VAF 35/181 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as COSV54919103; called by muse, mutect2, varscan2
- NOA1 | c.104G>T p.R35M | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.11); catalogued as COSV51738195; called by muse, mutect2
- NOBOX | c.1322del p.P441Hfs*25 | Frame Shift Del (DEL) | VAF 19/61 reads (31%) | catalogued as rs753934412; called by mutect2, varscan2
- NOD2 | c.1583del p.P528Qfs*235 | Frame Shift Del (DEL) | VAF 57/301 reads (19%) | catalogued as rs754073471; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- NODAL | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 41/268 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.736); catalogued as rs146471900; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOL7 | c.714del p.K238Nfs*16 | Frame Shift Del (DEL) | VAF 20/100 reads (20%) | catalogued as rs544905440; called by mutect2, varscan2
- NOS3 | c.1319del p.G440Afs*64 | Frame Shift Del (DEL) | VAF 23/105 reads (22%) | catalogued as rs749517498, COSV52496454; called by mutect2, pindel, varscan2
- NOTCH3 | c.3314del p.G1105Afs*167 | Frame Shift Del (DEL) | VAF 22/100 reads (22%) | catalogued as COSV54635564; called by mutect2, pindel, varscan2
- NPAS2 | c.1922T>C p.L641P | Missense Mutation (SNP) | VAF 43/230 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.543); catalogued as rs1219704539; called by muse, mutect2, varscan2
- NPC1L1 | c.1627A>G p.M543V | Missense Mutation (SNP) | VAF 21/188 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.102); catalogued as rs1467378861; called by muse, mutect2, varscan2
- NPHP3 | c.3374G>A p.R1125Q | Missense Mutation (SNP) | VAF 60/316 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as rs767752387, COSV100447091; called by muse, mutect2, varscan2
- NR4A2 | c.950A>G p.Y317C | Missense Mutation (SNP) | VAF 100/486 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100277134; called by muse, mutect2, varscan2
- NR5A2 | c.119T>C p.V40A | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs1228952924; called by muse, mutect2, varscan2
- NRXN1 | c.4413G>T p.K1471N | Missense Mutation (SNP) | VAF 31/176 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100640878; called by muse, mutect2, varscan2
- NT5DC3 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1222229376, COSV104430489; called by muse, mutect2
- NTN1 | c.1096G>T p.G366C | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51480181; called by muse, mutect2, varscan2
- NTRK1 | c.817C>T p.R273W | Missense Mutation (SNP) | VAF 23/228 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs151334385; ClinVar: uncertain significance; called by mutect2, varscan2
- NTRK3 | c.2082G>T p.K694N | Missense Mutation (SNP) | VAF 61/382 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100713115; called by muse, mutect2, varscan2
- NTRK3 | c.1709C>T p.A570V | Missense Mutation (SNP) | VAF 65/316 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1233225505; called by muse, mutect2, varscan2
- NUDT10 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 53/248 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.184); catalogued as rs144496531, COSV62854307; called by muse, mutect2, varscan2
- NUFIP1 | c.1073C>A p.T358K | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs754999074, COSV64792230; called by muse, varscan2
- NUP160 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.319); catalogued as rs367769746; called by muse, mutect2, varscan2
- NXPH2 | c.139G>A p.V47M | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.024); catalogued as COSV99740353; called by muse, mutect2, varscan2
- OAS2 | c.1277del p.N426Tfs*14 | Frame Shift Del (DEL) | VAF 52/269 reads (19%) | catalogued as rs781171419; called by mutect2, pindel, varscan2
- OBSCN | c.13339G>A p.A4447T | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs757439441, COSV99479347; called by muse, mutect2, varscan2
- OBSL1 | c.5267G>A p.R1756H | Missense Mutation (SNP) | VAF 74/293 reads (25%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs1438926650; called by muse, mutect2, varscan2
- OLFML2B | c.2001del p.L668Sfs*57 | Frame Shift Del (DEL) | VAF 112/319 reads (35%) | catalogued as COSV54194578; called by mutect2, pindel, varscan2
- OLR1 | c.69del p.A24Lfs*19 | Frame Shift Del (DEL) | VAF 21/110 reads (19%) | catalogued as rs747703868; called by mutect2, pindel, varscan2
- OR10H1 | c.205T>A p.S69T | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as rs747593084; called by muse, varscan2
- OR10K1 | c.808C>A p.Q270K | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.168); catalogued as rs1293047738; called by muse, mutect2
- OR13C3 | c.388C>T p.Q130* | Nonsense Mutation (SNP) | VAF 59/352 reads (17%) | catalogued as COSV66166209; called by muse, mutect2, varscan2
- OR1L4 | c.269C>A p.T90K | Missense Mutation (SNP) | VAF 95/517 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.242); catalogued as rs930459875; called by muse, mutect2, varscan2
- OR1N2 | c.479T>C p.L160P | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1395347873; called by muse, mutect2, varscan2
- OR2T1 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs777922327, COSV63542686; called by muse, mutect2, varscan2
- OR4E2 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs376724041; called by muse, mutect2, varscan2
- OR4K15 | c.773C>T p.A258V (on ENST00000305051; = p.A234V on NM_001005486.1) | Missense Mutation (SNP) | VAF 53/245 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as rs750493574, COSV59300693; called by muse, mutect2, varscan2
- OR51B4 | c.233C>T p.T78I | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as COSV66516980; called by muse, mutect2, varscan2
- OR52I2 | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 98/621 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.057); catalogued as rs953907960; called by muse, varscan2
- OR56B1 | c.218G>A p.G73D | Missense Mutation (SNP) | VAF 18/390 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.613); catalogued as rs1284823817; called by muse, mutect2
- OR5A1 | c.88C>T p.L30F | Missense Mutation (SNP) | VAF 25/224 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.172); catalogued as rs774227701, COSV57377902; called by muse, mutect2, varscan2
- OR5AK2 | c.833A>G p.Y278C | Missense Mutation (SNP) | VAF 31/198 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1261630472; called by muse, mutect2, varscan2
- OR5D16 | c.557T>C p.L186P | Missense Mutation (SNP) | VAF 45/253 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs567385719; called by muse, mutect2, varscan2
- OR5F1 | c.701G>T p.R234M | Missense Mutation (SNP) | VAF 32/182 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV53548342; called by muse, mutect2, varscan2
- OR5T1 | c.67A>G p.M23V | Missense Mutation (SNP) | VAF 43/206 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs199766697, COSV57302575; called by muse, mutect2, varscan2
- OR5T3 | c.367G>T p.E123* | Nonsense Mutation (SNP) | VAF 67/331 reads (20%) | catalogued as COSV99079074; called by muse, mutect2, varscan2
- OR6B3 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 70/260 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as rs373710002, COSV60112535; called by muse, mutect2, varscan2
- OSBPL1A | c.2378del p.N793Mfs*15 (on ENST00000319481 / NM_080597.4; = p.N280Mfs*15 on NM_018030.4) | Frame Shift Del (DEL) | VAF 36/130 reads (28%) | catalogued as rs751106039; called by mutect2, varscan2
- OTOG | c.2565del p.G856Efs*18 | Frame Shift Del (DEL) | VAF 50/214 reads (23%) | catalogued as rs1316007041, COSV61132740; called by mutect2, pindel, varscan2
- OXER1 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 56/264 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs771327290; called by muse, mutect2, varscan2
- OXNAD1 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 46/213 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs191814958, COSV53267037; called by muse, mutect2, varscan2
- P2RY2 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 47/196 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1276338491, COSV100232810; called by muse, mutect2, varscan2
- PAK6 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs765747411; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.408del p.S137Afs*37 (on ENST00000259318 / NM_001136562.3; = p.S368Afs*37 on NM_007203.5) | Frame Shift Del (DEL) | VAF 32/179 reads (18%) | catalogued as rs1564325849; called by mutect2, pindel, varscan2
- PANK2 | c.283C>T p.L95F | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.003); catalogued as rs558404718; called by muse, mutect2, varscan2
- PARD3 | c.1843G>A p.A615T | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.04); catalogued as rs774764458, COSV100400645; called by muse, mutect2, varscan2
- PARP14 | c.3965del p.N1322Ifs*26 | Frame Shift Del (DEL) | VAF 32/100 reads (32%) | catalogued as rs758945932; called by mutect2, varscan2
- PAX5 | c.224del p.T75Kfs*8 | Frame Shift Del (DEL) | VAF 27/181 reads (15%) | catalogued as COSV63904802, COSV63914497; called by mutect2, pindel, varscan2
- PCDH10 | c.2333G>A p.R778H | Missense Mutation (SNP) | VAF 48/269 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.791); catalogued as rs780537925, COSV52101461; called by muse, varscan2
- PCDH17 | c.1399G>A p.D467N | Missense Mutation (SNP) | VAF 57/361 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64974223; called by muse, mutect2, varscan2
- PCDHA1 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 61/344 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.011); catalogued as COSV65376089; called by muse, mutect2, varscan2
- PCDHA13 | c.1301C>T p.S434L | Missense Mutation (SNP) | VAF 69/478 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.453); catalogued as rs781786717, COSV56509806; called by muse, mutect2, varscan2
- PCDHA2 | c.1542C>A p.S514R | Missense Mutation (SNP) | VAF 90/645 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV65371052; called by muse, mutect2, varscan2
- PCDHA9 | c.2284G>A p.E762K | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.573); catalogued as rs1554144905, COSV100970249; called by muse, mutect2, varscan2
- PCDHGA11 | c.1889C>T p.A630V | Missense Mutation (SNP) | VAF 26/254 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.506); catalogued as rs374000303; called by muse, mutect2
- PCDHGA3 | c.1681G>A p.E561K | Missense Mutation (SNP) | VAF 37/494 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.133); catalogued as COSV53902853, COSV54066637; called by muse, mutect2
- PCDHGB3 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs1459915067; called by muse, mutect2
- PCDHGB5 | c.1901C>T p.A634V | Missense Mutation (SNP) | VAF 46/315 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.098); catalogued as COSV53953100; called by muse, mutect2, varscan2
- PCNX2 | c.1856dup p.E620Gfs*7 | Frame Shift Ins (INS) | VAF 18/87 reads (21%) | catalogued as rs1260749913; called by mutect2, varscan2
- PDE1B | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 23/98 reads (23%) | catalogued as rs1163489816, COSV54492739; called by muse, mutect2, varscan2
- PDZD2 | c.5800C>T p.R1934W | Missense Mutation (SNP) | VAF 33/176 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs751086010; called by muse, mutect2, varscan2
- PDZD4 | c.1885C>T p.R629C | Missense Mutation (SNP) | VAF 13/174 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51246768; called by muse, mutect2
- PEG3 | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV55634565; called by muse, mutect2, varscan2
- PEG3 | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs750191135, COSV55624847; called by muse, mutect2, varscan2
- PELP1 | c.2392del p.L798Cfs*14 | Frame Shift Del (DEL) | VAF 21/102 reads (21%) | catalogued as rs752653446, COSV99342923; called by mutect2, pindel, varscan2
- PEX2 | c.584T>C p.L195P | Missense Mutation (SNP) | VAF 14/368 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs995161736; called by muse, mutect2
- PFN4 | c.381del p.G128Efs*38 | Frame Shift Del (DEL) | VAF 21/174 reads (12%) | catalogued as COSV57531609; called by mutect2, varscan2
- PHF3 | c.5759G>A p.R1920H | Missense Mutation (SNP) | VAF 50/190 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs755576463, COSV100012840; called by muse, mutect2, varscan2
- PIF1 | c.618G>T p.Q206H | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as COSV51421427; called by muse, mutect2, varscan2
- PIK3CD | c.2537C>T p.A846V | Missense Mutation (SNP) | VAF 87/417 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.705); catalogued as COSV63129304; called by muse, mutect2, varscan2
- PIK3CG | c.667G>A p.V223I | Missense Mutation (SNP) | VAF 63/385 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as rs554272230, COSV63247299; called by muse, mutect2, varscan2
- PIP4P2 | c.635G>A p.G212D | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs73694351; called by muse, mutect2, varscan2
- PIP5K1C | c.706G>A p.V236M | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs377291771, COSV58950241; called by muse, mutect2
- PITX3 | c.662G>C p.G221A | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs1473811943; called by muse, mutect2, varscan2
- PKHD1L1 | c.6067G>A p.G2023R | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs747646955, COSV65747248; called by muse, mutect2, varscan2
- PKHD1L1 | c.6563del p.G2188Efs*28 | Frame Shift Del (DEL) | VAF 25/136 reads (18%) | catalogued as rs772426616; called by mutect2, pindel, varscan2
- PLAG1 | c.551del p.K184Sfs*45 | Frame Shift Del (DEL) | VAF 55/389 reads (14%) | catalogued as rs141930943; called by mutect2, pindel, varscan2
- PLAU | c.521G>A p.R174K | Missense Mutation (SNP) | VAF 35/213 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs1475683422; called by muse, mutect2, varscan2
- PLBD2 | c.614G>A p.G205E | Missense Mutation (SNP) | VAF 33/186 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.408); catalogued as rs910940553, COSV55106584; called by muse, mutect2, varscan2
- PLCB4 | c.2044C>T p.R682W | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1485973570, COSV53810146; called by muse, mutect2, varscan2
- PLCG1 | c.2333G>A p.R778H | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.416); catalogued as rs1027449153, COSV99719114; called by muse, mutect2, varscan2
- PLD1 | c.1021G>A p.G341R | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.946); catalogued as COSV60568546; called by muse, mutect2, varscan2
- PLD3 | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.93); catalogued as rs551176741, COSV62926109; called by muse, mutect2, varscan2
- PLD4 | c.1055del p.P352Rfs*57 | Frame Shift Del (DEL) | VAF 11/40 reads (28%) | catalogued as rs778485913; called by mutect2, pindel, varscan2
- PLEC | c.9659G>A p.R3220H (on ENST00000322810 / NM_201380.4; = p.R3110H on NM_000445.5) | Missense Mutation (SNP) | VAF 58/418 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as rs201948649, COSV59646588; called by muse, varscan2
- PLEC | c.5120C>T p.A1707V (on ENST00000322810 / NM_201380.4; = p.A1597V on NM_000445.5) | Missense Mutation (SNP) | VAF 109/261 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); catalogued as rs782096342; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEKHD1 | c.866G>A p.R289Q | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs772161082; called by muse, mutect2, varscan2
- PLEKHO1 | c.31G>T p.G11* | Nonsense Mutation (SNP) | VAF 12/100 reads (12%) | catalogued as COSV50311425; called by muse, varscan2
- PLG | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 121/457 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767909495; called by muse, mutect2, varscan2
- PLPP5 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1432007509, COSV57667188; called by muse, mutect2, varscan2
- PLPPR3 | c.1070A>G p.D357G (on ENST00000520876 / NM_001270366.2; = p.D385G on NM_024888.2) | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as COSV100608872; called by muse, mutect2, varscan2
- PMEL | c.1798G>A p.V600M | Missense Mutation (SNP) | VAF 50/220 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.123); catalogued as rs746474705, COSV59386459; called by muse, mutect2, varscan2
- PMFBP1 | c.2774G>A p.G925D (on ENST00000537465; = p.G920D on NM_031293.3) | Missense Mutation (SNP) | VAF 12/191 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1271966054; called by muse, mutect2
- PNISR | c.1733G>A p.R578H | Missense Mutation (SNP) | VAF 48/231 reads (21%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs750505657; called by muse, mutect2, varscan2
- PNMA3 | c.261del p.W89Gfs*3 | Frame Shift Del (DEL) | VAF 48/199 reads (24%) | catalogued as COSV64722654; called by mutect2, pindel, varscan2
- PNPLA2 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 119/484 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs554737718, CM1211338; called by muse, mutect2, varscan2
- PNPLA6 | c.259+8C>T | Splice Region (SNP) | VAF 38/171 reads (22%) | catalogued as rs1192261762; called by muse, mutect2, varscan2
- PNPLA7 | c.3522del p.I1175Sfs*148 | Frame Shift Del (DEL) | VAF 13/61 reads (21%) | catalogued as rs761459630; called by mutect2, pindel, varscan2
- POC1B-GALNT4 | c.1336C>T p.R446C | Missense Mutation (SNP) | VAF 69/248 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs766568348; called by muse, mutect2, varscan2
- POLD3 | c.898del p.R300Gfs*5 | Frame Shift Del (DEL) | VAF 15/58 reads (26%) | catalogued as rs761423306, COSV55240660; called by mutect2, varscan2
- POLR1G | c.653del p.N218Ifs*4 | Frame Shift Del (DEL) | VAF 39/206 reads (19%) | catalogued as rs753626854; called by mutect2, varscan2
- POLR2B | c.1774C>T p.R592C | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1316726875; called by muse, mutect2, varscan2
- POMC | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 57/319 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs562658963; called by muse, mutect2, varscan2
- POSTN | c.1522C>T p.R508C | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs753830117, COSV65714455; called by muse, mutect2, varscan2
- POTEE | c.3215G>A p.R1072H | Missense Mutation (SNP) | VAF 25/169 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.07); catalogued as rs1247402800; called by muse, mutect2, varscan2
- POTEF | c.2182del p.R728Gfs*16 | Frame Shift Del (DEL) | VAF 76/432 reads (18%) | catalogued as COSV62541836; called by mutect2, varscan2
- POTEF | c.294G>T p.M98I | Missense Mutation (SNP) | VAF 92/512 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs750446868; called by muse, mutect2, varscan2
- POTEH | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 67/957 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.591); catalogued as rs1186914043; called by muse, mutect2
- POTEI | c.1388A>G p.N463S | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1416911528; called by muse, mutect2
- POU3F3 | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated, low confidence (0.53); PolyPhen possibly damaging (0.739); catalogued as rs1392314847; called by muse, varscan2
- POU6F2 | c.344del p.P115Qfs*17 | Frame Shift Del (DEL) | VAF 21/131 reads (16%) | catalogued as COSV68869266; called by mutect2, pindel, varscan2
- PPM1F | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs549205418, COSV54283229; called by muse, mutect2, varscan2
- PPP1R14C | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as rs766379125, COSV100744829, COSV63173202; called by muse, mutect2, varscan2
2,899 further variants in this file (1,675 protein-altering or splice-affecting, 752 silent, 472 other) are not listed here.
